Somatic mutation profile of cancer-model specimen HCM-CSHL-0729-C18-85A (3D Organoid, passage 2; aliquot HCM-CSHL-0729-C18-85A-01D-A82I-36), derived from the primary tumor of HCMI case HCM-CSHL-0729-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: GB; Age at diagnosis: 60.0 years (21,919 days).
Specimen HCM-CSHL-0729-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 2.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c710ba3d-93ec-466f-8f0a-36a62faf06d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0729-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0729-C18-10A-01D-A82I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/41002e4d-708d-4dd3-9f2d-315199068b3a

The open-access MAF lists 1,572 somatic variants for this specimen: 1,301 protein-altering or splice-affecting, 210 silent, 61 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,007, Nonsense Mutation 248, Silent 210, Intron 42, Frame Shift Ins 20, Splice Region 9, 3'UTR 6, Translation Start Site 5, 5'Flank 4, Frame Shift Del 4, RNA 4, Splice Site 4.

Variants (750 of 1,572; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 111/292 reads (38%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- BRCA1 | c.5191G>T p.E1731* | Nonsense Mutation (SNP) | VAF 5/35 reads (14%) | catalogued as rs397507244, COSV100523074, COSV99070442; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- CTLA4 | c.60G>A p.W20* | Nonsense Mutation (SNP) | VAF 168/361 reads (47%) | catalogued as rs886041906, COSV55591750, COSV99865404; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.380G>T p.G127V | Missense Mutation (SNP) | VAF 145/336 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs398123322, COSV64289089, COSV64294277; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABHD18 | c.909G>T p.M303I (on ENST00000398965 / NM_001039717.2; = p.M210I on NM_025097.2 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 161/347 reads (46%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV66292975; called by muse, mutect2, varscan2
- ACAA2 | c.498G>T p.E166D | Missense Mutation (SNP) | VAF 152/333 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV99551704; called by muse, mutect2, varscan2
- ACOX1 | c.153G>T p.L51F | Missense Mutation (SNP) | VAF 24/507 reads (5%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV53133830, COSV53135592; called by muse, mutect2
- ACVR1C | c.996A>T p.K332N | Missense Mutation (SNP) | VAF 144/280 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54645046; called by muse, mutect2, varscan2
- ADAM20 | c.111C>A p.F37L | Missense Mutation (SNP) | VAF 152/338 reads (45%) | SIFT tolerated (0.72); PolyPhen benign (0.009); catalogued as COSV56456746; called by muse, mutect2, varscan2
- ADAM22 | c.1563C>A p.S521R | Missense Mutation (SNP) | VAF 84/191 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV55974834; called by muse, mutect2, varscan2
- ADGRE3 | c.340G>T p.E114* | Nonsense Mutation (SNP) | VAF 103/207 reads (50%) | catalogued as COSV53734782; called by muse, mutect2, varscan2
- ADGRG7 | c.786C>A p.F262L | Missense Mutation (SNP) | VAF 100/321 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751437270, COSV56301212, COSV99840688; called by muse, mutect2, varscan2
- ADGRV1 | c.8461G>T p.E2821* | Nonsense Mutation (SNP) | VAF 131/295 reads (44%) | catalogued as COSV67994316; called by muse, mutect2, varscan2
- ADRA1B | c.870G>T p.K290N | Missense Mutation (SNP) | VAF 164/369 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60704291; called by muse, mutect2, varscan2
- AGL | c.2847G>T p.K949N | Missense Mutation (SNP) | VAF 10/217 reads (5%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV54051877, COSV54059445; called by muse, mutect2
- AGTR1 | c.701G>T p.R234I | Missense Mutation (SNP) | VAF 55/105 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV62558999; called by muse, mutect2, varscan2
- AKAP9 | c.6221A>G p.Q2074R (on ENST00000359028; = p.Q2042R on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as rs762427337; called by muse, mutect2, varscan2
- AMER1 | c.1627G>T p.E543* | Nonsense Mutation (SNP) | VAF 42/756 reads (6%) | catalogued as COSV57663510; called by muse, mutect2
- AMER1 | c.971C>A p.S324* | Nonsense Mutation (SNP) | VAF 269/587 reads (46%) | catalogued as COSV57665666; called by muse, mutect2, varscan2
- ANK1 | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 91/199 reads (46%) | catalogued as COSV55874984, COSV55880954; called by muse, mutect2, varscan2
- ANO4 | c.311G>T p.R104I (on ENST00000392977 / NM_001286615.2; = p.R69I on NM_178826.4) | Missense Mutation (SNP) | VAF 83/182 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV54591769; called by muse, mutect2, varscan2
- AP002512.3 | c.581C>A p.T194N | Missense Mutation (SNP) | VAF 128/288 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); catalogued as COSV54405568; called by muse, mutect2
- AP002748.5 | c.541G>T p.E181* | Nonsense Mutation (SNP) | VAF 79/159 reads (50%) | catalogued as COSV59148777; called by muse, mutect2, varscan2
- APC | c.2937G>T p.M979I | Missense Mutation (SNP) | VAF 122/237 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV57332823; called by muse, mutect2, varscan2
- APOB | c.13159G>T p.E4387* | Nonsense Mutation (SNP) | VAF 48/120 reads (40%) | catalogued as COSV51922117; called by muse, mutect2, varscan2
- APOB | c.12835G>T p.E4279* | Nonsense Mutation (SNP) | VAF 36/139 reads (26%) | catalogued as COSV51928518; called by muse, mutect2, varscan2
- ARAP2 | c.539C>A p.S180* | Nonsense Mutation (SNP) | VAF 117/221 reads (53%) | catalogued as COSV58283400; called by muse, mutect2, varscan2
- AREG | c.244G>T p.D82Y | Missense Mutation (SNP) | VAF 187/442 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV99144390; called by muse, mutect2, varscan2
- ARFGEF2 | c.3977T>G p.V1326G | Missense Mutation (SNP) | VAF 108/246 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1263411905; called by muse, mutect2, varscan2
- ARL5B | c.47-1G>T p.X16_splice | Splice Site (SNP) | VAF 14/33 reads (42%) | catalogued as rs780550323, COSV66011521; called by muse, mutect2, varscan2
- ART3 | c.643C>A p.L215I | Missense Mutation (SNP) | VAF 134/298 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.232); catalogued as rs947944389; called by muse, mutect2, varscan2
- ASB17 | c.775C>A p.L259I | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as rs1184873256; called by muse, mutect2, varscan2
- ASIC5 | c.506T>G p.F169C | Missense Mutation (SNP) | VAF 147/305 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV72232857; called by muse, mutect2, varscan2
- ASMT | c.987C>A p.F329L (on ENST00000381229; = p.F357L on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 259/550 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV67110398; called by muse, mutect2, varscan2
- ASXL3 | c.2425G>A p.E809K | Missense Mutation (SNP) | VAF 188/389 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.149); catalogued as rs749484741, COSV52457610; called by muse, mutect2, varscan2
- ATF7-NPFF | c.1285A>G p.T429A | Missense Mutation (SNP) | VAF 158/374 reads (42%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs768475017; called by muse, mutect2, varscan2
- ATP6V1FNB | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 189/413 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.262); catalogued as rs1422813927; called by muse, mutect2, varscan2
- B2M | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 181/402 reads (45%) | catalogued as COSV62563605; called by muse, mutect2, varscan2
- B2M | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 170/426 reads (40%) | catalogued as COSV62563917; called by muse, varscan2
- BAZ1A | c.667A>G p.K223E | Missense Mutation (SNP) | VAF 62/190 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as rs771856136; called by muse, mutect2, varscan2
- BCAP31 | c.371C>A p.S124* | Nonsense Mutation (SNP) | VAF 115/273 reads (42%) | catalogued as COSV61452492; called by muse, mutect2, varscan2
- BCL2L11 | c.574C>T p.R192C (on ENST00000393256 / NM_138621.5; = p.R132C on NM_006538.5) | Missense Mutation (SNP) | VAF 119/275 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs758817904, COSV58027602; called by muse, mutect2, varscan2
- BCR | c.1942G>A p.D648N | Missense Mutation (SNP) | VAF 198/400 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100005938; called by muse, mutect2, varscan2
- BORCS8 | c.51C>A p.F17L | Missense Mutation (SNP) | VAF 155/308 reads (50%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs1363024959; called by muse, mutect2, varscan2
- BRAF | c.2330G>A p.G777D (on ENST00000288602 / NM_001374244.1; = p.G737D on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 177/421 reads (42%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.997); catalogued as rs778872326; called by muse, mutect2, varscan2
- BRCA1 | c.733G>T p.D245Y | Missense Mutation (SNP) | VAF 165/365 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs147519994; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BTK | c.238C>A p.P80T | Missense Mutation (SNP) | VAF 76/202 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as COSV58118418; called by mutect2, varscan2
- BTN1A1 | c.952C>G p.L318V | Missense Mutation (SNP) | VAF 144/303 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.301); catalogued as COSV55067190; called by muse, mutect2, varscan2
- C10orf53 | c.189C>A p.F63L | Missense Mutation (SNP) | VAF 196/532 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV65107584; called by muse, mutect2
- C2orf42 | c.51G>T p.L17F | Missense Mutation (SNP) | VAF 127/274 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52451947; called by muse, mutect2, varscan2
- C7orf31 | c.1387C>A p.H463N | Missense Mutation (SNP) | VAF 133/278 reads (48%) | SIFT tolerated (0.99); PolyPhen benign (0.023); catalogued as COSV52219915; called by mutect2, varscan2
- C8G | c.458G>T p.R153L | Missense Mutation (SNP) | VAF 125/288 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1163095078; called by muse, mutect2, varscan2
- C8orf34 | c.678G>T p.L226F | Missense Mutation (SNP) | VAF 30/446 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV61375421; called by muse, mutect2
- CA1 | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 131/308 reads (43%) | catalogued as rs373804439, COSV56277599; called by muse, mutect2, varscan2
- CAMK1G | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 132/312 reads (42%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.606); catalogued as rs144255822; called by muse, mutect2, varscan2
- CARMIL2 | c.4295G>T p.G1432V | Missense Mutation (SNP) | VAF 168/483 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as COSV54667834; called by muse, mutect2, varscan2
- CARS2 | c.1372G>T p.E458* | Nonsense Mutation (SNP) | VAF 89/233 reads (38%) | catalogued as COSV57284217; called by muse, mutect2, varscan2
- CASD1 | c.2005G>T p.E669* | Nonsense Mutation (SNP) | VAF 63/187 reads (34%) | catalogued as COSV51970648; called by muse, mutect2, varscan2
- CCDC148 | c.1387G>T p.E463* | Nonsense Mutation (SNP) | VAF 13/304 reads (4%) | catalogued as COSV51760638; called by muse, mutect2
- CCDC166 | c.1163C>T p.P388L | Missense Mutation (SNP) | VAF 112/826 reads (14%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as rs1005566324, COSV101545872; called by muse, mutect2, varscan2
- CCDC168 | c.979G>T p.E327* | Nonsense Mutation (SNP) | VAF 143/309 reads (46%) | catalogued as COSV70555535; called by muse, mutect2, varscan2
- CCDC39 | c.152G>T p.R51L | Missense Mutation (SNP) | VAF 52/142 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as rs749525425, COSV56477817, COSV56484645; called by muse, mutect2, varscan2
- CCT6B | c.1351C>A p.L451I | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as COSV58490898; called by muse, mutect2
- CCT8L2 | c.1066G>A p.G356R | Missense Mutation (SNP) | VAF 207/414 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs1166565426; called by muse, mutect2, varscan2
- CD209 | c.348G>T p.E116D | Missense Mutation (SNP) | VAF 300/676 reads (44%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.771); catalogued as COSV99214213; called by muse, varscan2
- CD300LG | c.70G>T p.E24* | Nonsense Mutation (SNP) | VAF 135/292 reads (46%) | catalogued as COSV53225399, COSV53225599; called by muse, mutect2, varscan2
- CDC27 | c.2274G>T p.M758I | Missense Mutation (SNP) | VAF 106/261 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.779); catalogued as COSV50677156; called by muse, mutect2, varscan2
- CDH6 | c.2170G>T p.D724Y | Missense Mutation (SNP) | VAF 30/544 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1379020867; called by muse, mutect2
- CDH8 | c.688C>A p.P230T | Missense Mutation (SNP) | VAF 110/219 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.042); catalogued as COSV100181039; called by muse, mutect2, varscan2
- CDK8 | c.451G>T p.D151Y | Missense Mutation (SNP) | VAF 108/207 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV101037399, COSV67419346; called by muse, mutect2, varscan2
- CENPF | c.444T>G p.I148M | Missense Mutation (SNP) | VAF 133/267 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.06); catalogued as COSV65279976; called by muse, mutect2, varscan2
- CENPJ | c.3730G>T p.E1244* | Nonsense Mutation (SNP) | VAF 77/152 reads (51%) | catalogued as COSV55045835; called by muse, mutect2, varscan2
- CEP192 | c.717G>T p.M239I | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.104); catalogued as rs1226789959; called by mutect2, varscan2
- CEP72 | c.173C>A p.S58Y | Missense Mutation (SNP) | VAF 133/322 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53791565; called by muse, mutect2, varscan2
- CFAP54 | c.8558dup p.L2854Pfs*2 | Frame Shift Ins (INS) | VAF 85/234 reads (36%) | catalogued as rs1347360579; called by mutect2, pindel, varscan2
- CHAF1A | c.508G>T p.A170S | Missense Mutation (SNP) | VAF 238/487 reads (49%) | SIFT tolerated (0.74); PolyPhen benign (0.058); catalogued as COSV56675073; called by muse, mutect2, varscan2
- CHD8 | c.241G>T p.E81* | Nonsense Mutation (SNP) | VAF 182/411 reads (44%) | catalogued as rs1555318703; called by muse, mutect2, varscan2
- CHRNA9 | c.109G>T p.D37Y | Missense Mutation (SNP) | VAF 66/174 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs887313309; called by muse, mutect2
- CHST15 | c.1540G>A p.A514T | Missense Mutation (SNP) | VAF 186/408 reads (46%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.837); catalogued as rs202236206, COSV60562996; called by muse, mutect2, varscan2
- CLASP2 | c.2488C>A p.P830T | Missense Mutation (SNP) | VAF 130/269 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.176); catalogued as rs755187415; called by muse, mutect2, varscan2
- CLDN20 | c.504C>A p.F168L | Missense Mutation (SNP) | VAF 176/384 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.472); catalogued as rs1391123602, COSV65697255, COSV65697705; called by muse, mutect2, varscan2
- CLEC14A | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 147/313 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60564115; called by muse, mutect2, varscan2
- CLHC1 | c.1543G>T p.E515* | Nonsense Mutation (SNP) | VAF 44/88 reads (50%) | catalogued as rs1469147865; called by muse, mutect2
- CNTN5 | c.1739G>T p.R580I | Missense Mutation (SNP) | VAF 26/232 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.951); catalogued as rs192113012, COSV54347282; called by muse, mutect2, varscan2
- CNTN6 | c.237G>T p.L79F | Missense Mutation (SNP) | VAF 47/347 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); catalogued as COSV63167967; called by muse, mutect2, varscan2
- CNTNAP4 | c.2914G>T p.G972* | Nonsense Mutation (SNP) | VAF 208/399 reads (52%) | catalogued as COSV56681470; called by muse, mutect2
- COL12A1 | c.2425G>T p.A809S | Missense Mutation (SNP) | VAF 66/119 reads (55%) | SIFT tolerated (0.23); PolyPhen benign (0.053); catalogued as COSV59389646; called by muse, mutect2, varscan2
- COL14A1 | c.788G>T p.G263V | Missense Mutation (SNP) | VAF 28/358 reads (8%) | SIFT tolerated (0.92); PolyPhen probably damaging (1); catalogued as rs764261501, COSV52856428; called by muse, mutect2
- COL15A1 | c.4135G>A p.E1379K | Missense Mutation (SNP) | VAF 113/267 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as rs755450632; called by muse, varscan2
- COL6A5 | c.1465G>T p.D489Y | Missense Mutation (SNP) | VAF 114/258 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.236); catalogued as COSV55194974; called by muse, mutect2, varscan2
- COL6A5 | c.2251C>A p.L751I | Missense Mutation (SNP) | VAF 161/334 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.906); catalogued as rs1371007654, COSV55199121; called by muse, mutect2, varscan2
- COL6A5 | c.6820C>A p.P2274T (on ENST00000312481; = p.P2270T on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.356); catalogued as COSV99594306; called by mutect2, varscan2
- CPS1 | c.3733C>A p.L1245I | Missense Mutation (SNP) | VAF 103/192 reads (54%) | SIFT tolerated (1); PolyPhen possibly damaging (0.583); catalogued as COSV51817311; called by muse, mutect2, varscan2
- CRELD2 | c.898dup p.T300Nfs*22 | Frame Shift Ins (INS) | VAF 154/388 reads (40%) | catalogued as rs1215550833; called by mutect2, pindel, varscan2
- CRISPLD1 | c.68C>A p.A23D | Missense Mutation (SNP) | VAF 204/415 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as COSV100081988; called by muse, mutect2, varscan2
- CRTAC1 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 282/548 reads (51%) | SIFT tolerated (0.26); PolyPhen benign (0.07); catalogued as rs199517598; called by muse, mutect2, varscan2
- CSNK2A1 | c.811G>T p.D271Y | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV53937777, COSV99424750; called by muse, mutect2, varscan2
- CTNNA3 | c.2211G>T p.M737I | Missense Mutation (SNP) | VAF 121/279 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs192848934; called by muse, mutect2, varscan2
- CYFIP2 | c.2032G>T p.E678* (on ENST00000616178 / NM_001291722.2; = p.E653* on NM_014376.4) | Nonsense Mutation (SNP) | VAF 153/285 reads (54%) | catalogued as COSV100556449; called by muse, mutect2, varscan2
- CYP11B1 | c.119C>A p.A40D | Missense Mutation (SNP) | VAF 208/497 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.976); catalogued as COSV52827157, COSV99455544; called by muse, mutect2, varscan2
- CYP4A22 | c.682G>T p.V228F | Missense Mutation (SNP) | VAF 180/344 reads (52%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs772583047, COSV53739901; called by muse, mutect2, varscan2
- DAB1 | c.1500G>T p.L500F (on ENST00000371231; = p.L467F on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 198/371 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as COSV64696727; called by muse, mutect2, varscan2
- DAZAP2 | c.305C>A p.S102Y | Missense Mutation (SNP) | VAF 139/321 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV66313265; called by muse, mutect2, varscan2
- DCAF4L2 | c.710C>A p.P237H | Missense Mutation (SNP) | VAF 190/392 reads (48%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); catalogued as COSV60477762, COSV60480991; called by muse, mutect2, varscan2
- DCLK3 | c.1305G>T p.Q435H | Missense Mutation (SNP) | VAF 14/366 reads (4%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.667); catalogued as COSV69364191, COSV99067416; called by muse, mutect2
- DEPDC4 | c.544G>T p.E182* | Nonsense Mutation (SNP) | VAF 30/84 reads (36%) | catalogued as COSV54552923; called by muse, mutect2, varscan2
- DIPK1A | c.367G>T p.D123Y | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV64792667; called by muse, mutect2, varscan2
- DISP1 | c.4375G>T p.E1459* | Nonsense Mutation (SNP) | VAF 142/295 reads (48%) | catalogued as COSV52654944; called by muse, mutect2, varscan2
- DMRT2 | c.1202C>T p.S401F | Missense Mutation (SNP) | VAF 269/518 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as rs1438193635; called by muse, mutect2
- DNAH3 | c.1261C>A p.H421N | Missense Mutation (SNP) | VAF 28/406 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.02); catalogued as COSV99770234; called by muse, mutect2
- DNAH8 | c.8083G>T p.V2695L | Missense Mutation (SNP) | VAF 130/244 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59486310; called by mutect2, varscan2
- DNAH8 | c.12986G>T p.R4329I | Missense Mutation (SNP) | VAF 129/275 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1221140553, COSV59435605, COSV59460628; called by muse, mutect2, varscan2
- DNTT | c.967C>A p.L323I | Missense Mutation (SNP) | VAF 33/479 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.658); catalogued as rs778131462; called by muse, mutect2
- DNTTIP2 | c.2021G>T p.R674I | Missense Mutation (SNP) | VAF 123/278 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63284373; called by muse, mutect2, varscan2
- DROSHA | c.3637C>T p.R1213C | Missense Mutation (SNP) | VAF 146/325 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV60772166; called by muse, mutect2, varscan2
- DYNC1I1 | c.242dup p.L81Ffs*28 | Frame Shift Ins (INS) | VAF 76/202 reads (38%) | catalogued as rs781167095; called by mutect2, pindel, varscan2
- DYNC1I1 | c.1276C>A p.P426T | Missense Mutation (SNP) | VAF 112/261 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61472410; called by muse, mutect2, varscan2
- DYNC2H1 | c.1173T>G p.I391M | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.192); catalogued as rs1286571022; called by muse, mutect2, varscan2
- EBF3 | c.558C>A p.F186L | Missense Mutation (SNP) | VAF 108/208 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV62475179; called by muse, mutect2, varscan2
- EDDM3B | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 132/282 reads (47%) | catalogued as COSV58747030; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1959C>A p.F653L | Missense Mutation (SNP) | VAF 124/254 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100668326, COSV62571229; called by muse, mutect2, varscan2
- EFCAB13 | c.508G>T p.E170* | Nonsense Mutation (SNP) | VAF 19/42 reads (45%) | catalogued as COSV58949123; called by muse, mutect2, varscan2
- EIF4EBP3 | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 265/523 reads (51%) | SIFT tolerated (0.31); PolyPhen benign (0.245); catalogued as rs781551674; called by muse, mutect2, varscan2
- EIF4G1 | c.1744C>A p.H582N (on ENST00000346169 / NM_198241.3; = p.H386N on NM_004953.5) | Missense Mutation (SNP) | VAF 47/337 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.085); catalogued as COSV59993787; called by muse, mutect2, varscan2
- ELOA2 | c.1985C>T p.A662V | Missense Mutation (SNP) | VAF 241/475 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1218680153; called by muse, mutect2, varscan2
- EP300 | c.4513G>T p.E1505* | Nonsense Mutation (SNP) | VAF 27/404 reads (7%) | catalogued as COSV54330446, COSV54348775; called by muse, mutect2
- EPB41L4A | c.813C>A p.F271L | Missense Mutation (SNP) | VAF 100/213 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV99813287; called by muse, mutect2, varscan2
- EPB41L4B | c.702T>A p.N234K | Missense Mutation (SNP) | VAF 158/320 reads (49%) | SIFT tolerated (0.42); PolyPhen benign (0.089); catalogued as rs944891415; called by muse, mutect2, varscan2
- EPHA3 | c.506G>T p.R169I | Missense Mutation (SNP) | VAF 136/342 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100341729; called by muse, mutect2, varscan2
- EPHA6 | c.649G>T p.E217* | Nonsense Mutation (SNP) | VAF 132/273 reads (48%) | catalogued as COSV67571138, COSV67578619; called by mutect2, varscan2
- EPS8 | c.2161A>G p.I721V | Missense Mutation (SNP) | VAF 164/356 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1336240695; called by muse, mutect2, varscan2
- ERBB3 | c.1747C>A p.P583T | Missense Mutation (SNP) | VAF 206/418 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as COSV57248919; called by muse, mutect2, varscan2
- ERC2 | c.869G>T p.R290I | Missense Mutation (SNP) | VAF 132/333 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55642390; called by muse, mutect2, varscan2
- ERCC6 | c.2281G>T p.E761* | Nonsense Mutation (SNP) | VAF 70/147 reads (48%) | catalogued as COSV100875766; called by muse, mutect2, varscan2
- ERICH3 | c.3142G>T p.E1048* | Nonsense Mutation (SNP) | VAF 147/298 reads (49%) | catalogued as rs145428486; called by muse, mutect2, varscan2
- ESAM | c.548T>A p.V183D | Missense Mutation (SNP) | VAF 213/424 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs779588823; called by muse, mutect2, varscan2
- F8 | c.5799G>T p.E1933D | Missense Mutation (SNP) | VAF 125/271 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV64269296; called by muse, mutect2, varscan2
- FADS6 | c.402C>A p.F134L | Missense Mutation (SNP) | VAF 144/297 reads (48%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as COSV59603038; called by muse, mutect2, varscan2
- FAM111B | c.874G>T p.E292* | Nonsense Mutation (SNP) | VAF 11/192 reads (6%) | catalogued as COSV59113431; called by muse, mutect2
- FAM160A2 | c.575C>A p.S192* | Nonsense Mutation (SNP) | VAF 301/630 reads (48%) | catalogued as COSV56412579; called by muse, mutect2, varscan2
- FAM3A | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 36/538 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782151076; called by muse, mutect2
- FASN | c.5404G>A p.E1802K | Missense Mutation (SNP) | VAF 197/452 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as rs764921764, COSV100148038; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBXO46 | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 285/622 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs770645321; called by muse, mutect2, varscan2
- FBXW10 | c.2406G>T p.K802N | Missense Mutation (SNP) | VAF 275/320 reads (86%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as rs766712663, COSV57059522; called by muse, mutect2, varscan2
- FCER1G | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 91/234 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.775); catalogued as COSV57156355; called by muse, mutect2
- FCRL2 | c.1036G>C p.A346P | Missense Mutation (SNP) | VAF 187/399 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1405874429, COSV63833904; called by muse, mutect2, varscan2
- FER1L6 | c.1020C>A p.F340L | Missense Mutation (SNP) | VAF 133/259 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV101205444; called by muse, mutect2, varscan2
- FIGNL1 | c.1579C>A p.Q527K | Missense Mutation (SNP) | VAF 122/258 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63553167; called by muse, mutect2, varscan2
- FLG | c.4067G>T p.R1356I | Missense Mutation (SNP) | VAF 20/490 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs1007909829, COSV64251766; called by muse, mutect2
- FLNC | c.3511G>A p.G1171S | Missense Mutation (SNP) | VAF 286/590 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.715); catalogued as rs769490872, COSV57953088; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FN1 | c.2943C>A p.S981R | Missense Mutation (SNP) | VAF 152/294 reads (52%) | SIFT tolerated (0.61); PolyPhen benign (0.143); catalogued as COSV60556085; called by muse, mutect2, varscan2
- FSIP2 | c.18558T>G p.F6186L | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.939); catalogued as rs1309357649; called by muse, mutect2, varscan2
- GABRG1 | c.170C>A p.P57Q | Missense Mutation (SNP) | VAF 88/241 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); catalogued as COSV54959931; called by muse, mutect2, varscan2
- GALNT8 | c.36C>A p.F12L | Missense Mutation (SNP) | VAF 19/335 reads (6%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV52894930; called by muse, mutect2
- GALNT9 | c.488C>T p.A163V | Missense Mutation (SNP) | VAF 220/453 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs781085284, COSV61097448; called by muse, mutect2, varscan2
- GANC | c.1860C>A p.F620L | Missense Mutation (SNP) | VAF 132/306 reads (43%) | PolyPhen probably damaging (0.999); catalogued as COSV58810893; called by muse, mutect2
- GAP43 | c.640G>T p.E214* | Nonsense Mutation (SNP) | VAF 73/158 reads (46%) | catalogued as COSV59344455; called by muse, mutect2, varscan2
- GGA3 | c.1976C>T p.P659L (on ENST00000537686 / NM_138619.4; = p.P626L on NM_014001.5) | Missense Mutation (SNP) | VAF 159/355 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs759820278; called by muse, mutect2, varscan2
- GLB1 | c.795C>A p.I265= | Splice Region (SNP) | VAF 130/247 reads (53%) | catalogued as rs1339270920; called by muse, mutect2, varscan2
- GLP2R | c.1257C>A p.F419L | Missense Mutation (SNP) | VAF 72/171 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.364); catalogued as COSV52324428; called by mutect2, varscan2
- GLRB | c.1420G>T p.D474Y | Missense Mutation (SNP) | VAF 107/256 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765701013; called by muse, mutect2, varscan2
- GNAO1 | c.715G>T p.E239* | Nonsense Mutation (SNP) | VAF 22/272 reads (8%) | catalogued as COSV52622115; called by muse, mutect2
- GPATCH8 | c.2390G>A p.R797Q | Missense Mutation (SNP) | VAF 215/413 reads (52%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs751449158, COSV59194287; called by muse, mutect2, varscan2
- GRAMD1B | c.837G>T p.K279N | Missense Mutation (SNP) | VAF 233/501 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as COSV59211920; called by muse, mutect2, varscan2
- GREB1 | c.1717C>A p.L573I | Missense Mutation (SNP) | VAF 106/249 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV52184393; called by muse, mutect2, varscan2
- GREB1L | c.1306G>T p.D436Y | Missense Mutation (SNP) | VAF 137/385 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.814); catalogued as COSV52556408; called by muse, mutect2, varscan2
- GRM8 | c.2067C>A p.F689L | Missense Mutation (SNP) | VAF 73/364 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as COSV58883132; called by muse, mutect2, varscan2
- GTF2B | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 105/269 reads (39%) | catalogued as COSV65136884; called by muse, mutect2, varscan2
- GZF1 | c.1532G>T p.R511I | Missense Mutation (SNP) | VAF 112/238 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57635707; called by muse, mutect2, varscan2
- HASPIN | c.2268G>T p.M756I | Missense Mutation (SNP) | VAF 20/469 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.172); catalogued as rs1463502468; called by muse, mutect2
- HDC | c.1092C>A p.F364L | Missense Mutation (SNP) | VAF 155/337 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51081508; called by muse, mutect2, varscan2
- HELQ | c.1788G>T p.M596I | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as rs1191301199, COSV55028472; called by muse, mutect2, varscan2
- HMGCLL1 | c.565G>T p.E189* | Nonsense Mutation (SNP) | VAF 108/254 reads (43%) | catalogued as COSV51451966; called by muse, mutect2, varscan2
- HNRNPF | c.1172G>T p.G391V | Missense Mutation (SNP) | VAF 197/367 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as COSV61561688; called by muse, mutect2, varscan2
- HP1BP3 | c.394dup p.T132Nfs*36 | Frame Shift Ins (INS) | VAF 150/290 reads (52%) | catalogued as rs1248069646; called by mutect2, varscan2
- HRNR | c.4447C>T p.R1483* | Nonsense Mutation (SNP) | VAF 201/312 reads (64%) | catalogued as rs1434822980; called by muse, mutect2, varscan2
- HTR3D | c.369C>A p.F123L (on ENST00000382489 / NM_001163646.2; = p.F62L on NM_001145143.1) | Missense Mutation (SNP) | VAF 106/244 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.225); catalogued as COSV61913191; called by muse, mutect2
- HTR7 | c.1056C>A p.F352L | Missense Mutation (SNP) | VAF 44/453 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV53286416; called by muse, mutect2, varscan2
- HTRA1 | c.1339G>T p.D447Y | Missense Mutation (SNP) | VAF 180/436 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1422468280; called by muse, mutect2, varscan2
- IDI1 | c.253G>T p.D85Y | Missense Mutation (SNP) | VAF 118/230 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777622677; called by muse, mutect2, varscan2
- IFT57 | c.758C>T p.T253M | Missense Mutation (SNP) | VAF 138/292 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as rs774931041, COSV52711861; called by muse, mutect2, varscan2
- IGBP1 | c.844G>T p.D282Y | Missense Mutation (SNP) | VAF 53/362 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV60556434; called by muse, mutect2, varscan2
- IGSF10 | c.5866G>T p.G1956W | Missense Mutation (SNP) | VAF 213/387 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56782471; called by muse, mutect2, varscan2
- IL18RAP | c.87dup p.L30Tfs*10 | Frame Shift Ins (INS) | VAF 83/155 reads (54%) | catalogued as rs756319084; called by mutect2, pindel*, varscan2
- IL7R | c.744G>T p.L248F | Missense Mutation (SNP) | VAF 130/335 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV57411421; called by muse, mutect2, varscan2
- INTU | c.1664G>T p.R555I | Missense Mutation (SNP) | VAF 129/267 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as rs774690451; called by muse, mutect2, varscan2
- ITGB2 | c.1850G>A p.R617H (on ENST00000302347; = p.R593H on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 299/620 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as rs749255547, COSV56608418; called by muse, varscan2
- JMY | c.1454C>A p.S485Y | Missense Mutation (SNP) | VAF 36/388 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV101268036; called by muse, mutect2
- KALRN | c.7891G>T p.D2631Y (on ENST00000360013 / NM_001024660.4; = p.D934Y on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 171/340 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52258370; called by muse, mutect2, varscan2
- KBTBD2 | c.1503T>G p.I501M | Missense Mutation (SNP) | VAF 201/400 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.29); catalogued as COSV100406565; called by muse, mutect2, varscan2
- KCNH7 | c.1322G>T p.R441I | Missense Mutation (SNP) | VAF 114/246 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as rs1251173767; called by muse, mutect2, varscan2
- KCNH8 | c.2082A>C p.S694= | Splice Region (SNP) | VAF 105/202 reads (52%) | catalogued as rs1301281983; called by muse, mutect2, varscan2
- KCNQ3 | c.1600T>A p.F534I | Missense Mutation (SNP) | VAF 82/189 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66467174; called by mutect2, varscan2
- KDM4E | c.1009C>A p.Q337K | Missense Mutation (SNP) | VAF 195/404 reads (48%) | SIFT tolerated (0.75); PolyPhen benign (0.234); catalogued as rs1390764735; called by muse, mutect2, varscan2
- KIAA1109 | c.12344G>T p.G4115V | Missense Mutation (SNP) | VAF 90/216 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV52678318; called by muse, mutect2, varscan2
- KIAA1671 | c.4655C>A p.A1552D | Missense Mutation (SNP) | VAF 133/265 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as rs773445204; called by muse, mutect2, varscan2
- KIF26B | c.3491C>A p.S1164Y | Missense Mutation (SNP) | VAF 283/554 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.259); catalogued as COSV63649141; called by mutect2, varscan2
- KLHDC2 | c.910A>C p.K304Q | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.659); catalogued as COSV100026899; called by mutect2, varscan2
- KNL1 | c.5419G>T p.E1807* (on ENST00000346991 / NM_170589.5; = p.E1781* on NM_144508.5) | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | catalogued as COSV61152792; called by muse, mutect2, varscan2
- KRT6B | c.857C>A p.A286D | Missense Mutation (SNP) | VAF 87/274 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs771623502, COSV52885484; called by muse, mutect2, varscan2
- KRTAP19-4 | c.237C>A p.F79L | Missense Mutation (SNP) | VAF 81/153 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV100478592; called by muse, mutect2, varscan2
- LAMP5 | c.136G>T p.D46Y | Missense Mutation (SNP) | VAF 194/366 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs777491312, COSV55718164; called by muse, mutect2, varscan2
- LARP1 | c.2579G>T p.G860V (on ENST00000518297 / NM_033551.3; = p.G783V on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 184/378 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as COSV60426584; called by muse, mutect2, varscan2
- LATS1 | c.2065G>T p.E689* | Nonsense Mutation (SNP) | VAF 30/96 reads (31%) | catalogued as COSV53590373, COSV53599929; called by muse, mutect2, varscan2
- LCP2 | c.1250C>A p.S417* | Nonsense Mutation (SNP) | VAF 37/82 reads (45%) | catalogued as COSV50448006; called by muse, mutect2, varscan2
- LCT | c.2110G>T p.D704Y | Missense Mutation (SNP) | VAF 182/375 reads (49%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.724); catalogued as COSV51552627; called by muse, mutect2, varscan2
- LINGO2 | c.226G>T p.E76* | Nonsense Mutation (SNP) | VAF 22/326 reads (7%) | catalogued as COSV58056349; called by muse, mutect2
- LMNTD1 | c.342G>T p.K114N | Missense Mutation (SNP) | VAF 64/135 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.738); catalogued as COSV51450721, COSV51450758; called by muse, mutect2, varscan2
- LONRF2 | c.695C>A p.S232* | Nonsense Mutation (SNP) | VAF 85/198 reads (43%) | catalogued as COSV66539347; called by muse, mutect2, varscan2
- LRP1B | c.12691G>T p.E4231* | Nonsense Mutation (SNP) | VAF 110/243 reads (45%) | catalogued as rs1419834168; called by muse, mutect2, varscan2
- LRRCC1 | c.1175C>T p.S392L | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.297); catalogued as rs749550564; called by muse, mutect2, varscan2
- LRRIQ3 | c.1490C>A p.A497D | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as rs1165254069, COSV63043917, COSV63045064; called by muse, mutect2, varscan2
- LVRN | c.2725T>G p.L909V | Missense Mutation (SNP) | VAF 115/274 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.228); catalogued as rs1320407013; called by muse, mutect2, varscan2
- MACF1 | c.2693C>A p.S898Y | Missense Mutation (SNP) | VAF 133/320 reads (42%) | catalogued as rs774515220, COSV58380576; called by muse, mutect2, varscan2
- MAGEC2 | c.323C>A p.S108* | Nonsense Mutation (SNP) | VAF 243/503 reads (48%) | catalogued as COSV55998321, COSV56002040; called by muse, mutect2, varscan2
- MAGEC3 | c.1345G>T p.E449* | Nonsense Mutation (SNP) | VAF 272/556 reads (49%) | catalogued as COSV53580537; called by muse, mutect2, varscan2
- MAGEC3 | c.1572C>A p.F524L | Missense Mutation (SNP) | VAF 217/434 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.044); catalogued as rs780880692, COSV100025945, COSV53577680; called by muse, mutect2, varscan2
- MAGI1 | c.2365C>A p.P789T | Missense Mutation (SNP) | VAF 147/277 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs770193154, COSV58322664; called by mutect2, varscan2
- MAP3K21 | c.1234G>T p.E412* | Nonsense Mutation (SNP) | VAF 14/393 reads (4%) | catalogued as COSV64043782; called by muse, mutect2
- MAP3K7 | c.1024A>G p.N342D | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.214); catalogued as rs749145408; called by muse, mutect2, varscan2
- MARK1 | c.2089C>A p.P697T | Missense Mutation (SNP) | VAF 145/355 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV65070121; called by muse, mutect2, varscan2
- MCM6 | c.1779C>A p.F593L | Missense Mutation (SNP) | VAF 86/203 reads (42%) | SIFT tolerated (0.79); PolyPhen benign (0.006); catalogued as COSV51469669; called by muse, mutect2, varscan2
- MEGF6 | c.3475G>A p.E1159K | Missense Mutation (SNP) | VAF 219/413 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); catalogued as rs764681187, COSV99619990; called by muse, mutect2, varscan2
- MEPE | c.61C>A p.Q21K | Missense Mutation (SNP) | VAF 86/202 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.167); catalogued as rs746510246; called by mutect2, varscan2
- MICALL1 | c.680C>T p.S227L | Missense Mutation (SNP) | VAF 218/580 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs777911238; called by muse, mutect2, varscan2
- MKLN1 | c.1792C>A p.H598N | Missense Mutation (SNP) | VAF 69/145 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs777468548, COSV61760448, COSV61761541; called by muse, mutect2, varscan2
- MMP13 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 180/203 reads (89%) | SIFT tolerated (0.07); PolyPhen benign (0.09); catalogued as rs189974040; called by muse, mutect2, varscan2
- MTF2 | c.8A>T p.D3V | Missense Mutation (SNP) | VAF 112/254 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.266); catalogued as COSV104427396; called by muse, mutect2, varscan2
- MTREX | c.1732G>T p.E578* | Nonsense Mutation (SNP) | VAF 57/133 reads (43%) | catalogued as COSV100043876; called by muse, mutect2, varscan2
- MUC16 | c.24541G>T p.E8181* | Nonsense Mutation (SNP) | VAF 224/444 reads (50%) | catalogued as COSV101201359; called by muse, mutect2, varscan2
- MUC16 | c.19059G>T p.M6353I | Missense Mutation (SNP) | VAF 135/296 reads (46%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); catalogued as COSV67475727; called by muse, mutect2, varscan2
- MUC16 | c.579G>T p.M193I | Missense Mutation (SNP) | VAF 208/416 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.06); catalogued as rs761616274, COSV67457388; called by muse, mutect2, varscan2
- MYH3 | c.3059C>A p.S1020Y | Missense Mutation (SNP) | VAF 180/332 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as rs770477653, COSV56862050; called by muse, mutect2, varscan2
- MYH9 | c.2033A>G p.K678R | Missense Mutation (SNP) | VAF 111/239 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1220725450; called by muse, mutect2, varscan2
- MYO10 | c.5349A>T p.K1783N | Missense Mutation (SNP) | VAF 18/326 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.059); catalogued as COSV99946673; called by muse, mutect2
- MYOC | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 170/366 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV50676446; called by muse, mutect2, varscan2
- MYPN | c.3711G>T p.K1237N | Missense Mutation (SNP) | VAF 180/395 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.816); catalogued as COSV62739404; called by muse, mutect2, varscan2
- NBEA | c.2211G>T p.M737I | Missense Mutation (SNP) | VAF 71/152 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV59773954, COSV59797102; called by muse, mutect2, varscan2
- NBEAL1 | c.1075A>G p.I359V | Missense Mutation (SNP) | VAF 72/196 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.143); catalogued as rs1279943714; called by muse, varscan2
- NBEAL1 | c.2592T>G p.I864M | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1377187978; called by muse, mutect2, varscan2
- NCBP2L | c.10G>T p.D4Y | Missense Mutation (SNP) | VAF 52/192 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.284); catalogued as COSV100966499; called by muse, mutect2, varscan2
- NCKAP5 | c.2572G>T p.E858* | Nonsense Mutation (SNP) | VAF 120/238 reads (50%) | catalogued as rs1239979798, COSV58444568; called by muse, varscan2
- NDST4 | c.1480G>T p.E494* | Nonsense Mutation (SNP) | VAF 60/143 reads (42%) | catalogued as COSV52134737; called by muse, mutect2, varscan2
- NET1 | c.490A>C p.M164L (on ENST00000355029 / NM_001047160.3; = p.M110L on NM_005863.5) | Missense Mutation (SNP) | VAF 178/353 reads (50%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs572860536; called by muse, mutect2, varscan2
- NF1 | c.7262A>C p.N2421T (on ENST00000358273 / NM_001042492.3; = p.N2400T on NM_000267.3) | Missense Mutation (SNP) | VAF 82/206 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs774339063; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NIPBL | c.1849G>T p.E617* | Nonsense Mutation (SNP) | VAF 92/190 reads (48%) | catalogued as COSV99240920; called by muse, mutect2, varscan2
- NLGN1 | c.1021G>T p.E341* | Nonsense Mutation (SNP) | VAF 54/347 reads (16%) | catalogued as COSV100848839; called by muse, mutect2, varscan2
- NOTCH1 | c.7234C>A p.P2412T | Missense Mutation (SNP) | VAF 468/902 reads (52%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV53052947; called by muse, mutect2, varscan2
- NPHP3 | c.785C>G p.S262C | Missense Mutation (SNP) | VAF 131/310 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.276); catalogued as COSV58129721; called by muse, mutect2, varscan2
- NSD2 | c.924T>G p.I308M | Missense Mutation (SNP) | VAF 113/238 reads (47%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.786); catalogued as rs760909823; called by muse, mutect2, varscan2
- NSUN6 | c.490G>T p.E164* | Nonsense Mutation (SNP) | VAF 24/76 reads (32%) | catalogued as rs774577958, COSV66031702; called by muse, mutect2, varscan2
- NUMA1 | c.3283G>T p.A1095S | Missense Mutation (SNP) | VAF 248/545 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.423); catalogued as rs1290384268; called by muse, mutect2, varscan2
- NYAP1 | c.1359dup p.K454Qfs*112 | Frame Shift Ins (INS) | VAF 158/434 reads (36%) | catalogued as rs1355570169; called by mutect2, varscan2
- OBSCN | c.15157G>A p.E5053K | Missense Mutation (SNP) | VAF 214/460 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs772564832; called by muse, varscan2
- OR10G4 | c.760T>C p.C254R | Missense Mutation (SNP) | VAF 199/392 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV57977941; called by muse, varscan2
- OR10J1 | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 188/384 reads (49%) | catalogued as COSV71128713; called by muse, varscan2
- OR10S1 | c.329G>T p.G110V | Missense Mutation (SNP) | VAF 69/441 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV73343052; called by muse, mutect2, varscan2
- OR11A1 | c.306C>A p.F102L | Missense Mutation (SNP) | VAF 105/667 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.217); catalogued as COSV101010722, COSV65821255; called by muse, mutect2, varscan2
- OR11H6 | c.853C>A p.P285T | Missense Mutation (SNP) | VAF 132/286 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.112); catalogued as rs760092591, COSV59644056; called by muse, mutect2, varscan2
- OR2M5 | c.618G>T p.M206I | Missense Mutation (SNP) | VAF 96/252 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as rs749940471, COSV63545804, COSV63546155, COSV99057361; called by muse, mutect2, varscan2
- OR2T10 | c.224C>A p.S75Y | Missense Mutation (SNP) | VAF 170/354 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.827); catalogued as COSV100393712; called by muse, mutect2, varscan2
- OR2T6 | c.805A>G p.I269V | Missense Mutation (SNP) | VAF 233/496 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs771583152; called by muse, varscan2
- OR2Z1 | c.36C>A p.F12L | Missense Mutation (SNP) | VAF 184/385 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV60692502; called by muse, mutect2, varscan2
- OR51G2 | c.849C>A p.F283L | Missense Mutation (SNP) | VAF 154/326 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.577); catalogued as COSV58991839; called by muse, mutect2, varscan2
- OR5AN1 | c.889G>T p.E297* | Nonsense Mutation (SNP) | VAF 43/86 reads (50%) | catalogued as rs1177245319; called by muse, mutect2, varscan2
- OR5D16 | c.778C>T p.L260F | Missense Mutation (SNP) | VAF 177/383 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as rs375832312, COSV65722636; called by muse, mutect2, varscan2
- OR5K1 | c.24G>T p.M8I | Missense Mutation (SNP) | VAF 101/230 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV60304375, COSV60304635; called by muse, mutect2, varscan2
- OR5K1 | c.684G>T p.M228I | Missense Mutation (SNP) | VAF 73/137 reads (53%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.85); catalogued as COSV60303853; called by muse, mutect2, varscan2
- OR6C70 | c.718T>C p.S240P | Missense Mutation (SNP) | VAF 58/153 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as rs1389412537; called by muse, mutect2, varscan2
- OSBP2 | c.961G>T p.D321Y | Missense Mutation (SNP) | VAF 274/516 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100212880; called by muse, mutect2, varscan2
- OTOG | c.3703A>C p.T1235P | Missense Mutation (SNP) | VAF 148/321 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs764534477; called by mutect2, varscan2
- P2RY10 | c.738C>A p.F246L | Missense Mutation (SNP) | VAF 235/484 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50680618; called by muse, mutect2, varscan2
- P4HB | c.308A>G p.K103R | Missense Mutation (SNP) | VAF 157/316 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs751445347; called by muse, mutect2, varscan2
- PACSIN2 | c.79A>T p.T27S | Missense Mutation (SNP) | VAF 194/379 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as rs1427224178; called by muse, mutect2, varscan2
- PAK5 | c.1687G>T p.G563* | Nonsense Mutation (SNP) | VAF 151/355 reads (43%) | catalogued as COSV62031633; called by muse, mutect2, varscan2
- PANX2 | c.850G>A p.V284M | Missense Mutation (SNP) | VAF 371/756 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV50304550; called by muse, mutect2, varscan2
- PARK7 | c.399G>T p.M133I | Missense Mutation (SNP) | VAF 70/161 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as CM144904; called by muse, mutect2, varscan2
- PATJ | c.893G>T p.G298V | Missense Mutation (SNP) | VAF 180/371 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV57155927; called by muse, mutect2, varscan2
- PCBP4 | c.1071C>A p.F357L (on ENST00000322099 / NM_033010.2; = p.F314L on NM_020418.4) | Missense Mutation (SNP) | VAF 315/720 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100436878; called by muse, mutect2, varscan2
- PCDH15 | c.1719G>T p.M573I | Missense Mutation (SNP) | VAF 134/281 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV57279486; called by muse, mutect2, varscan2
- PCDHB15 | c.1903G>C p.V635L | Missense Mutation (SNP) | VAF 462/897 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.101); catalogued as COSV50999990; called by muse, mutect2, varscan2
- PCDHGA9 | c.1217C>A p.T406K | Missense Mutation (SNP) | VAF 105/218 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV53916555; called by muse, mutect2, varscan2
- PCDHGB2 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 152/307 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1160500738; called by muse, mutect2, varscan2
- PDE11A | c.1375G>T p.E459* | Nonsense Mutation (SNP) | VAF 118/250 reads (47%) | catalogued as rs780484841, COSV53687032; called by muse, mutect2, varscan2
- PDS5B | c.905C>A p.A302E | Missense Mutation (SNP) | VAF 132/292 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as COSV100221223; called by muse, mutect2, varscan2
- PDXK | c.468A>T p.L156F | Missense Mutation (SNP) | VAF 30/526 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99376282; called by muse, mutect2
- PER3 | c.1670G>T p.R557I | Missense Mutation (SNP) | VAF 105/206 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62704786, COSV62707891; called by muse, mutect2, varscan2
- PEX13 | c.1010G>T p.R337I | Missense Mutation (SNP) | VAF 176/387 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV54371727; called by muse, mutect2, varscan2
- PHYHD1 | c.210C>A p.F70L | Missense Mutation (SNP) | VAF 138/300 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.904); catalogued as rs201188576; called by muse, mutect2, varscan2
- PIBF1 | c.158G>T p.R53L | Missense Mutation (SNP) | VAF 98/233 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1454565631, COSV58327467; called by muse, mutect2, varscan2
- PIK3C2G | c.2701G>T p.E901* (on ENST00000676171; = p.E860* on NM_004570.5) | Nonsense Mutation (SNP) | VAF 9/156 reads (6%) | catalogued as COSV56816951, COSV56831913; called by muse, mutect2
- PIK3R1 | c.1465G>T p.E489* (on ENST00000521381 / NM_181523.3; = p.E219* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 151/152 reads (99%) | catalogued as CM136437, COSV57128610; called by muse, mutect2, varscan2
- PKD1L3 | c.4499G>T p.R1500I | Missense Mutation (SNP) | VAF 90/194 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as rs1009872899; called by mutect2, varscan2
- PLA2R1 | c.2069G>T p.R690I | Missense Mutation (SNP) | VAF 14/355 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51778743; called by muse, mutect2
- PLAG1 | c.141G>T p.E47D | Missense Mutation (SNP) | VAF 149/313 reads (48%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.952); catalogued as COSV57614746; called by muse, mutect2, varscan2
- PLEKHG4B | c.3349G>T p.E1117* (on ENST00000283426; = p.E1473* on NM_052909.5) | Nonsense Mutation (SNP) | VAF 124/289 reads (43%) | catalogued as COSV99361543; called by muse, mutect2, varscan2
- PLPPR4 | c.2113G>A p.V705I | Missense Mutation (SNP) | VAF 158/437 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.543); catalogued as rs1428243344, COSV64567018; called by muse, mutect2, varscan2
- PMS2 | c.1753C>A p.L585I | Missense Mutation (SNP) | VAF 130/286 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.043); catalogued as rs63750947, COSV56220451, COSV99763837; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- PNPLA6 | c.4072C>A p.L1358I (on ENST00000414982 / NM_001166111.2; = p.L1310I on NM_006702.5) | Missense Mutation (SNP) | VAF 76/489 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as rs1225642722, COSV55372870, COSV55375569; called by muse, mutect2, varscan2
- POLE | c.5609G>A p.R1870H | Missense Mutation (SNP) | VAF 134/267 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs758619238, COSV100268743; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLE | c.784G>T p.D262Y | Missense Mutation (SNP) | VAF 36/411 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs754730369; called by muse, mutect2
- POLH | c.955A>G p.I319V | Missense Mutation (SNP) | VAF 144/323 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as rs1377543277; called by muse, mutect2, varscan2
- POM121L12 | c.360G>T p.M120I | Missense Mutation (SNP) | VAF 291/668 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.141); catalogued as COSV68693043; called by muse, mutect2, varscan2
- POU3F4 | c.139C>A p.P47T | Missense Mutation (SNP) | VAF 235/466 reads (50%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV100937351, COSV64539271; called by muse, mutect2, varscan2
- PPP1R3C | c.462G>T p.K154N | Missense Mutation (SNP) | VAF 142/292 reads (49%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.502); catalogued as rs769285267; called by muse, mutect2, varscan2
- PRAMEF2 | c.777C>A p.F259L | Missense Mutation (SNP) | VAF 98/219 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs529323357, COSV53577332; called by muse, mutect2, varscan2
- PRKD2 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 120/297 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as rs1459489245; called by muse, mutect2, varscan2
- PRR30 | c.351G>T p.W117C | Missense Mutation (SNP) | VAF 250/526 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as rs1452295363; called by muse, mutect2, varscan2
- PTEN | c.878G>T p.G293V | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV64288924, COSV64295414; called by muse, mutect2, varscan2
- PTPN23 | c.2034C>A p.F678L | Missense Mutation (SNP) | VAF 238/501 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs551844731; called by muse, mutect2, varscan2
- PTPRB | c.575C>A p.S192Y | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV54245447; called by muse, mutect2, varscan2
- PTRHD1 | c.35T>G p.V12G | Missense Mutation (SNP) | VAF 40/560 reads (7%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs1224905354, COSV53229371; called by muse, mutect2
- PUS10 | c.372C>A p.F124L | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.194); catalogued as COSV57454358; called by muse, mutect2
- QRICH1 | c.1415C>A p.S472Y | Missense Mutation (SNP) | VAF 148/341 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as COSV62614643; called by muse, mutect2, varscan2
- RAG1 | c.350C>A p.S117Y | Missense Mutation (SNP) | VAF 203/424 reads (48%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.107); catalogued as rs1279281327, COSV55024702; called by muse, mutect2, varscan2
- RALGAPA1 | c.1636G>T p.E546* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as COSV51895967; called by mutect2, varscan2
- RASA1 | c.829-1G>T p.X277_splice | Splice Site (SNP) | VAF 30/90 reads (33%) | catalogued as CS1311715; called by mutect2, varscan2
- RASA1 | c.1160C>A p.S387* | Nonsense Mutation (SNP) | VAF 76/237 reads (32%) | catalogued as COSV57199924; called by muse, mutect2, varscan2
- RB1 | c.2712G>T p.M904I | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.074); catalogued as rs1461167778, COSV57297074, COSV57328407; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- RFC1 | c.1865C>A p.S622Y | Missense Mutation (SNP) | VAF 35/335 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.058); catalogued as COSV100567360; called by muse, mutect2
- RHOH | c.434C>A p.A145D | Missense Mutation (SNP) | VAF 286/564 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67806466; called by muse, mutect2, varscan2
- RLF | c.5402C>A p.S1801Y | Missense Mutation (SNP) | VAF 96/199 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); catalogued as rs903296426, COSV65653296; called by muse, mutect2, varscan2
- RNF111 | c.698T>G p.L233* | Nonsense Mutation (SNP) | VAF 94/95 reads (99%) | catalogued as COSV62085532; called by muse, mutect2, varscan2
- RP1 | c.4130A>G p.D1377G | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.815); catalogued as rs1332588522; called by muse, mutect2, varscan2
- RPAP2 | c.613G>T p.E205* | Nonsense Mutation (SNP) | VAF 93/207 reads (45%) | catalogued as COSV72509310; called by muse, mutect2, varscan2
- RPH3A | c.916C>A p.P306T (on ENST00000389385 / NM_001143854.2; = p.P302T on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 209/461 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV101231829; called by muse, mutect2
- RPUSD2 | c.967G>T p.E323* | Nonsense Mutation (SNP) | VAF 183/346 reads (53%) | catalogued as COSV59765287; called by muse, mutect2, varscan2
- RTN1 | c.694A>C p.K232Q | Missense Mutation (SNP) | VAF 204/409 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99956824; called by muse, mutect2, varscan2
- RUNX1T1 | c.1558C>T p.R520C (on ENST00000265814 / NM_001198628.1; = p.R493C on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 146/355 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99754826; called by muse, mutect2, varscan2
- RXFP2 | c.917A>T p.N306I | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.296); catalogued as COSV100034458; called by muse, mutect2, varscan2
- RXRA | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 191/384 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs779808577; called by muse, mutect2, varscan2
- SACS | c.7408G>T p.D2470Y | Missense Mutation (SNP) | VAF 108/216 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV66533535; called by muse, mutect2, varscan2
- SALL2 | c.2909C>A p.A970D | Missense Mutation (SNP) | VAF 231/452 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.462); catalogued as rs368220424, COSV58101844; called by muse, mutect2, varscan2
- SALL2 | c.2317G>T p.E773* | Nonsense Mutation (SNP) | VAF 229/488 reads (47%) | catalogued as rs1311309013, COSV58106262; called by muse, mutect2, varscan2
- SAMHD1 | c.173G>T p.G58V | Missense Mutation (SNP) | VAF 20/509 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV53429959; called by muse, mutect2
- SASH1 | c.1036G>T p.A346S | Missense Mutation (SNP) | VAF 37/503 reads (7%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.009); catalogued as COSV66561368; called by muse, mutect2
- SBNO1 | c.916G>T p.E306* (on ENST00000420886; = p.E305* on NM_018183.5) | Nonsense Mutation (SNP) | VAF 93/233 reads (40%) | catalogued as COSV57342611; called by muse, mutect2, varscan2
- SCAF4 | c.1918G>T p.E640* | Nonsense Mutation (SNP) | VAF 141/321 reads (44%) | catalogued as COSV54590275; called by muse, mutect2, varscan2
- SCAI | c.1522C>T p.R508* (on ENST00000336505 / NM_001144877.3; = p.R531* on NM_173690.5) | Nonsense Mutation (SNP) | VAF 156/308 reads (51%) | catalogued as COSV57176039; called by muse, mutect2, varscan2
- SCTR | c.373G>A p.V125I | Missense Mutation (SNP) | VAF 186/391 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs149693113; called by muse, mutect2, varscan2
- SEC23A | c.72G>T p.W24C | Missense Mutation (SNP) | VAF 123/297 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV56976702; called by muse, mutect2, varscan2
- SEMA3D | c.2274G>T p.K758N | Missense Mutation (SNP) | VAF 167/331 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV52391816, COSV52392691; called by muse, mutect2, varscan2
- SEMA4D | c.1591G>T p.A531S | Missense Mutation (SNP) | VAF 227/474 reads (48%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as COSV59391553; called by muse, mutect2, varscan2
- SERINC3 | c.1009A>C p.N337H | Missense Mutation (SNP) | VAF 128/286 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV54855791; called by muse, mutect2, varscan2
- SERPINB12 | c.913G>T p.E305* | Nonsense Mutation (SNP) | VAF 20/351 reads (6%) | catalogued as rs374065223; called by muse, mutect2
- SETD1A | c.3613C>T p.R1205W | Missense Mutation (SNP) | VAF 338/696 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); catalogued as rs775350343, COSV99353939; called by muse, mutect2, varscan2
- SETD4 | c.398T>G p.L133* | Nonsense Mutation (SNP) | VAF 22/447 reads (5%) | catalogued as COSV100145575; called by muse, mutect2
- SF3B2 | c.508C>A p.H170N | Missense Mutation (SNP) | VAF 164/347 reads (47%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV100488533; called by muse, mutect2, varscan2
- SFPQ | c.1153G>T p.E385* | Nonsense Mutation (SNP) | VAF 146/371 reads (39%) | catalogued as COSV100599510, COSV61758332; called by muse, mutect2, varscan2
- SGK1 | c.673C>A p.P225T | Missense Mutation (SNP) | VAF 88/181 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52816001; called by muse, mutect2, varscan2
- SGK1 | c.229C>A p.P77T | Missense Mutation (SNP) | VAF 110/237 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV52804532; called by mutect2, varscan2
- SGK3 | c.739G>T p.E247* | Nonsense Mutation (SNP) | VAF 36/66 reads (55%) | catalogued as COSV61897148; called by muse, mutect2, varscan2
- SH3GLB1 | c.229G>T p.E77* | Nonsense Mutation (SNP) | VAF 25/143 reads (17%) | catalogued as COSV65279067; called by muse, mutect2, varscan2
- SH3KBP1 | c.488G>T p.G163V | Missense Mutation (SNP) | VAF 161/357 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.244); catalogued as COSV65640986; called by muse, mutect2, varscan2
- SH3RF1 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 185/431 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs755358542; called by muse, mutect2, varscan2
- SIDT2 | c.2137G>T p.D713Y | Missense Mutation (SNP) | VAF 147/371 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54056037, COSV54058632; called by muse, mutect2, varscan2
- SLC10A6 | c.1124C>A p.S375* | Nonsense Mutation (SNP) | VAF 145/311 reads (47%) | catalogued as COSV99907295; called by muse, mutect2, varscan2
- SLC12A1 | c.2892C>A p.S964R | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.477); catalogued as rs1430596489; called by muse, mutect2, varscan2
- SLC16A6 | c.1176T>G p.F392L | Missense Mutation (SNP) | VAF 143/309 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); catalogued as rs782733542; called by muse, mutect2, varscan2
- SLC24A1 | c.1551C>A p.F517L | Missense Mutation (SNP) | VAF 195/397 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56053059, COSV56053894; called by muse, mutect2, varscan2
- SLC27A6 | c.1515C>A p.F505L | Missense Mutation (SNP) | VAF 66/166 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as COSV99323568; called by muse, mutect2, varscan2
- SLC4A9 | c.409G>T p.A137S (on ENST00000507527 / NM_001258428.2; = p.A113S on NM_031467.3) | Missense Mutation (SNP) | VAF 242/495 reads (49%) | SIFT tolerated (0.65); PolyPhen benign (0.119); catalogued as rs756451645; called by muse, varscan2
- SLC6A16 | c.110C>A p.S37* | Nonsense Mutation (SNP) | VAF 218/430 reads (51%) | catalogued as COSV60030520; called by muse, mutect2, varscan2
- SLC8A1 | c.1535C>A p.A512D | Missense Mutation (SNP) | VAF 134/344 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.035); catalogued as COSV60491946; called by muse, mutect2, varscan2
- SLC8A3 | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 182/356 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as rs766322163, COSV63526605; called by muse, mutect2, varscan2
- SLITRK3 | c.732G>T p.K244N | Missense Mutation (SNP) | VAF 188/361 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as COSV53845266, COSV53846493; called by muse, mutect2, varscan2
- SLITRK4 | c.1219C>A p.H407N | Missense Mutation (SNP) | VAF 27/413 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62022890, COSV62025657; called by muse, mutect2
- SMG7 | c.1788G>T p.K596N | Missense Mutation (SNP) | VAF 89/214 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.289); catalogued as COSV61630700; called by muse, mutect2, varscan2
- SNCB | c.176C>A p.T59N | Missense Mutation (SNP) | VAF 159/324 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.393); catalogued as rs779230513, COSV59435914; called by muse, mutect2, varscan2
- SNX1 | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 146/322 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as rs1426456011; called by muse, mutect2, varscan2
- SOBP | c.2265G>T p.K755N | Missense Mutation (SNP) | VAF 124/478 reads (26%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as COSV58003669; called by muse, varscan2
- SORBS3 | c.26G>T p.R9L | Missense Mutation (SNP) | VAF 199/410 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs146179804; called by muse, mutect2, varscan2
- SOX11 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 174/376 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100431061; called by muse, mutect2, varscan2
- SPIDR | c.815G>T p.R272L | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52373754; called by muse, mutect2, varscan2
- SPOCK3 | c.1102G>T p.E368* | Nonsense Mutation (SNP) | VAF 130/383 reads (34%) | catalogued as COSV62732055; called by muse, mutect2, varscan2
- SRRM4 | c.1791C>A p.S597R | Missense Mutation (SNP) | VAF 311/652 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV99937760; called by muse, mutect2, varscan2
- STAB2 | c.6744G>T p.W2248C | Missense Mutation (SNP) | VAF 161/415 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1004434876; called by muse, mutect2, varscan2
- STARD9 | c.8846G>T p.R2949I | Missense Mutation (SNP) | VAF 155/339 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs1363358955; called by muse, mutect2, varscan2
- STEAP4 | c.562G>T p.E188* | Nonsense Mutation (SNP) | VAF 209/408 reads (51%) | catalogued as COSV57331145; called by muse, mutect2, varscan2
- STK31 | c.2091G>T p.Q697H | Missense Mutation (SNP) | VAF 69/191 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as COSV63459557; called by muse, mutect2, varscan2
- SWT1 | c.2437C>A p.Q813K | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.386); catalogued as COSV62256173; called by muse, varscan2
- SYCP2 | c.2242G>T p.D748Y | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV62770266; called by muse, mutect2, varscan2
- SYMPK | c.1183A>G p.T395A | Missense Mutation (SNP) | VAF 216/448 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1347777046; called by muse, mutect2, varscan2
- SYNE3 | c.901G>T p.E301* | Nonsense Mutation (SNP) | VAF 235/487 reads (48%) | catalogued as COSV62082777; called by muse, mutect2, varscan2
- SYNM | c.4645G>T p.A1549S (on ENST00000336292 / NM_145728.3; = p.A1237S on NM_015286.6) | Missense Mutation (SNP) | VAF 99/266 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782156525; called by muse, mutect2, varscan2
- SYNPO2 | c.1211C>A p.A404D | Missense Mutation (SNP) | VAF 20/416 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61108830; called by muse, mutect2
- SYT4 | c.267G>T p.K89N | Missense Mutation (SNP) | VAF 133/274 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV54898241, COSV99674071; called by muse, mutect2, varscan2
- SYTL3 | c.607T>A p.S203T | Missense Mutation (SNP) | VAF 28/249 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as rs978023990; called by muse, mutect2, varscan2
- TAOK3 | c.352C>A p.P118T | Missense Mutation (SNP) | VAF 115/245 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as rs1328458063, COSV66825383; called by muse, mutect2, varscan2
- TBC1D8B | c.3032C>A p.S1011* | Nonsense Mutation (SNP) | VAF 22/216 reads (10%) | catalogued as COSV52177141; called by muse, mutect2, varscan2
- TENM3 | c.5208G>T p.M1736I | Missense Mutation (SNP) | VAF 208/428 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101305208; called by muse, mutect2, varscan2
- TEX47 | c.85A>G p.N29D | Missense Mutation (SNP) | VAF 143/296 reads (48%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs1211714115; called by muse, mutect2, varscan2
- TGS1 | c.1510C>A p.P504T | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs765414360; called by muse, mutect2, varscan2
- TIMM22 | c.527C>A p.A176D | Missense Mutation (SNP) | VAF 23/327 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.224); catalogued as rs1233181867; called by muse, mutect2
- TIMP3 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 245/512 reads (48%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs200592407; called by muse, mutect2, varscan2
- TKT | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 221/455 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.429); catalogued as rs782390818; called by muse, mutect2, varscan2
- TLK1 | c.913A>G p.T305A | Missense Mutation (SNP) | VAF 208/416 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as rs1335662117; called by muse, mutect2, varscan2
- TLN2 | c.6259G>T p.D2087Y | Missense Mutation (SNP) | VAF 181/352 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1057460564; called by muse, mutect2, varscan2
- TMEM232 | c.1525G>T p.E509* | Nonsense Mutation (SNP) | VAF 11/40 reads (28%) | catalogued as COSV70265504; called by muse, mutect2, varscan2
- TMOD1 | c.614T>A p.I205N | Missense Mutation (SNP) | VAF 22/274 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs755685627; called by muse, mutect2
- TRAF4 | c.1195G>T p.A399S | Missense Mutation (SNP) | VAF 270/531 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52218010; called by muse, mutect2, varscan2
- TREM1 | c.378C>A p.F126L | Missense Mutation (SNP) | VAF 146/286 reads (51%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.586); catalogued as rs772655224, COSV55148210, COSV55148868; called by muse, mutect2, varscan2
- TRIM71 | c.1987G>A p.A663T | Missense Mutation (SNP) | VAF 245/466 reads (53%) | SIFT tolerated (0.49); PolyPhen benign (0.051); catalogued as rs1310080218; called by muse, mutect2, varscan2
- TRMT1L | c.372C>A p.C124* | Nonsense Mutation (SNP) | VAF 77/248 reads (31%) | catalogued as rs752067642; called by muse, mutect2, varscan2
- TRPM5 | c.873C>A p.F291L | Missense Mutation (SNP) | VAF 174/387 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.236); catalogued as rs1184515027, COSV50144870; called by muse, mutect2, varscan2
- TSHZ1 | c.1478C>A p.S493Y (on ENST00000580243 / NM_001308210.2; = p.S448Y on NM_005786.6) | Missense Mutation (SNP) | VAF 211/423 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as COSV59010139; called by muse, mutect2, varscan2
- TSHZ2 | c.1803G>T p.K601N | Missense Mutation (SNP) | VAF 155/391 reads (40%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV61589723, COSV61590270, COSV61590733; called by muse, mutect2, varscan2
- TTN | c.98305G>T p.E32769* (on ENST00000591111; = p.E25345* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 133/296 reads (45%) | catalogued as COSV60168668; called by muse, mutect2, varscan2
- TTN | c.40807G>T p.E13603* (on ENST00000591111; = p.E6179* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 143/310 reads (46%) | catalogued as COSV60134666; called by muse, mutect2, varscan2
- TTN | c.32313G>T p.K10771N (on ENST00000591111; = p.K9844N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/106 reads (42%) | PolyPhen benign (0.322); catalogued as COSV100614515; called by muse, mutect2, varscan2
- TTN | c.28712C>A p.S9571* (on ENST00000591111; = p.S8644* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 32/96 reads (33%) | catalogued as COSV60197728; called by mutect2, varscan2
- UBLCP1 | c.115C>A p.L39I | Missense Mutation (SNP) | VAF 98/200 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.886); catalogued as rs1448101670, COSV57142644; called by muse, mutect2, varscan2
- UPK1B | c.356A>G p.N119S | Missense Mutation (SNP) | VAF 68/172 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.253); catalogued as COSV51767162; called by muse, mutect2, varscan2
- URGCP | c.948G>T p.W316C (on ENST00000453200 / NM_001077663.3; = p.W307C on NM_017920.4) | Missense Mutation (SNP) | VAF 187/405 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs768644545, COSV56245878; called by muse, mutect2, varscan2
- USP34 | c.2959C>A p.R987S | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV68400704; called by muse, mutect2, varscan2
- USP37 | c.1510G>T p.D504Y | Missense Mutation (SNP) | VAF 21/195 reads (11%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.998); catalogued as COSV51447052; called by muse, mutect2, varscan2
- USP51 | c.1122G>T p.M374I | Missense Mutation (SNP) | VAF 137/322 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1427903383, COSV72351621; called by muse, mutect2, varscan2
- USPL1 | c.2703G>T p.K901N | Missense Mutation (SNP) | VAF 124/268 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.711); catalogued as COSV54999805, COSV55001029; called by muse, mutect2, varscan2
- UTP14A | c.34G>T p.A12S | Missense Mutation (SNP) | VAF 47/333 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.35); catalogued as rs777902752; called by muse, mutect2, varscan2
- VNN1 | c.816G>T p.K272N | Missense Mutation (SNP) | VAF 100/178 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100907751; called by mutect2, varscan2
- VPS33B | c.969G>T p.M323I | Missense Mutation (SNP) | VAF 50/326 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.355); catalogued as COSV60980268; called by muse, mutect2, varscan2
- WDCP | c.578G>A p.R193K | Missense Mutation (SNP) | VAF 190/417 reads (46%) | SIFT tolerated (0.8); PolyPhen benign (0.011); catalogued as COSV54592943; called by muse, mutect2, varscan2
- WFDC1 | c.618G>T p.K206N | Missense Mutation (SNP) | VAF 148/292 reads (51%) | SIFT tolerated (0.44); PolyPhen benign (0.026); catalogued as COSV54745733; called by muse, mutect2, varscan2
- WNK3 | c.3545G>T p.G1182V | Missense Mutation (SNP) | VAF 27/446 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as COSV63615284; called by muse, mutect2
- YTHDF3 | c.209C>A p.S70Y | Missense Mutation (SNP) | VAF 174/351 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV72773399; called by muse, mutect2, varscan2
- ZBTB11 | c.2325C>A p.F775L | Missense Mutation (SNP) | VAF 133/266 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs758124325, COSV100465510, COSV57246578; called by muse, mutect2, varscan2
- ZBTB43 | c.508G>T p.E170* | Nonsense Mutation (SNP) | VAF 34/489 reads (7%) | catalogued as COSV65095175; called by muse, mutect2
- ZHX2 | c.561G>T p.M187I | Missense Mutation (SNP) | VAF 166/412 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV58711489; called by muse, mutect2, varscan2
- ZKSCAN7 | c.2216G>T p.R739L | Missense Mutation (SNP) | VAF 186/401 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV56272188; called by muse, mutect2, varscan2
- ZMAT3 | c.280C>A p.H94N | Missense Mutation (SNP) | VAF 36/199 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60995399; called by muse, mutect2, varscan2
- ZMYM5 | c.934G>T p.E312* | Nonsense Mutation (SNP) | VAF 17/46 reads (37%) | catalogued as COSV61987755; called by muse, mutect2, varscan2
- ZNF157 | c.1149G>T p.E383D | Missense Mutation (SNP) | VAF 43/432 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV65658423; called by muse, mutect2, varscan2
- ZNF17 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 26/557 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1287264301; called by muse, mutect2
- ZNF214 | c.984G>T p.E328D | Missense Mutation (SNP) | VAF 81/179 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as COSV53483439; called by muse, mutect2, varscan2
- ZNF226 | c.688G>T p.E230* | Nonsense Mutation (SNP) | VAF 127/234 reads (54%) | catalogued as rs1399159138; called by muse, mutect2, varscan2
- ZNF229 | c.2335C>T p.R779C | Missense Mutation (SNP) | VAF 169/379 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.942); catalogued as rs759283205; called by muse, mutect2, varscan2
- ZNF256 | c.1828A>C p.K610Q | Missense Mutation (SNP) | VAF 13/399 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV56597246, COSV99990780; called by muse, mutect2
- ZNF404 | c.956G>T p.R319I | Missense Mutation (SNP) | VAF 94/205 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.97); catalogued as rs1167607351, COSV60988924; called by muse, mutect2, varscan2
- ZNF419 | c.731C>A p.S244Y | Missense Mutation (SNP) | VAF 111/243 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.077); catalogued as rs763862940; called by muse, mutect2, varscan2
- ZNF430 | c.1267C>A p.H423N | Missense Mutation (SNP) | VAF 57/123 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55110576; called by muse, mutect2, varscan2
- ZNF440 | c.1652C>A p.P551H | Missense Mutation (SNP) | VAF 116/335 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV58370513; called by muse, mutect2, varscan2
- ZNF461 | c.913G>T p.E305* | Nonsense Mutation (SNP) | VAF 123/267 reads (46%) | catalogued as COSV100831535; called by muse, mutect2, varscan2
- ZNF492 | c.1154G>T p.R385I | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as rs551588064, COSV71761672, COSV71761738; called by muse, mutect2, varscan2
- ZNF568 | c.1318C>T p.R440* | Nonsense Mutation (SNP) | VAF 169/382 reads (44%) | catalogued as rs770596753, COSV101426806; called by muse, mutect2, varscan2
- ZNF582 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 24/118 reads (20%) | catalogued as rs778511522; called by muse, mutect2, varscan2
- ZNF630 | c.332C>A p.S111* | Nonsense Mutation (SNP) | VAF 113/232 reads (49%) | catalogued as COSV52095852; called by muse, mutect2, varscan2
- ZNF667 | c.1065G>T p.E355D | Missense Mutation (SNP) | VAF 108/256 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.455); catalogued as rs1287171553, COSV52631050, COSV52637836; called by muse, mutect2, varscan2
- ZNF692 | c.953G>T p.R318I | Missense Mutation (SNP) | VAF 91/176 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100133832; called by muse, mutect2, varscan2
- ZNF700 | c.1669A>C p.T557P | Missense Mutation (SNP) | VAF 20/350 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as rs1398285984; called by muse, mutect2
- ZNF730 | c.743G>T p.R248I | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT tolerated (0.66); PolyPhen benign (0.012); catalogued as COSV101659646, COSV74168366; called by muse, mutect2, varscan2
- ZNF850 | c.1322G>T p.R441L | Missense Mutation (SNP) | VAF 28/371 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as COSV74024680; called by muse, mutect2
- ZNF850 | c.266C>A p.S89* | Nonsense Mutation (SNP) | VAF 91/202 reads (45%) | catalogued as rs1223213187; called by muse, mutect2, varscan2
- ZNF91 | c.2504T>G p.F835C | Missense Mutation (SNP) | VAF 65/145 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104394847; called by muse, mutect2, varscan2
- ZNF98 | c.689G>T p.R230I | Missense Mutation (SNP) | VAF 116/258 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.021); catalogued as COSV63334241; called by muse, mutect2, varscan2
- AAMP | c.268C>G p.H90D | Missense Mutation (SNP) | VAF 140/319 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AARS2 | c.110C>A p.A37D | Missense Mutation (SNP) | VAF 323/694 reads (47%) | SIFT tolerated (0.63); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- AASDH | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 17/193 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.766); called by muse, mutect2
- ABCA7 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 184/432 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.14); called by muse, mutect2
- ABCF1 | c.852C>A p.F284L (on ENST00000326195 / NM_001025091.2; = p.F246L on NM_001090.3) | Missense Mutation (SNP) | VAF 233/502 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABHD13 | c.606G>T p.L202F | Missense Mutation (SNP) | VAF 88/213 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ABI1 | c.44G>T p.G15V | Missense Mutation (SNP) | VAF 238/439 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AC092718.8 | c.177G>T p.W59C | Missense Mutation (SNP) | VAF 96/209 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); called by mutect2, varscan2
- AC126283.2 | c.920T>G p.L307W | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- ACADS | c.213G>T p.V71= | Splice Region (SNP) | VAF 197/447 reads (44%) | called by muse, mutect2, varscan2
- ACOX1 | c.1593C>A p.C531* | Nonsense Mutation (SNP) | VAF 70/150 reads (47%) | called by mutect2, varscan2
- ACSM5 | c.899T>A p.V300D | Missense Mutation (SNP) | VAF 142/271 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- ACTL8 | c.832G>T p.E278* | Nonsense Mutation (SNP) | VAF 279/630 reads (44%) | called by muse, mutect2, varscan2
- ACVR1 | c.241T>C p.C81R | Missense Mutation (SNP) | VAF 193/403 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM17 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 41/628 reads (7%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.147); called by muse, mutect2
- ADAM23 | c.1102A>T p.M368L | Missense Mutation (SNP) | VAF 162/392 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ADAMDEC1 | c.106A>G p.T36A | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ADCY10 | c.3157A>C p.I1053L | Missense Mutation (SNP) | VAF 110/272 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADCY8 | c.2815G>T p.E939* | Nonsense Mutation (SNP) | VAF 155/371 reads (42%) | called by muse, mutect2, varscan2
- ADGB | c.3612G>T p.K1204N | Missense Mutation (SNP) | VAF 28/355 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); called by muse, mutect2
- ADGRF5 | c.828C>A p.F276L | Missense Mutation (SNP) | VAF 25/320 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2
- ADGRV1 | c.13709G>T p.R4570I | Missense Mutation (SNP) | VAF 133/307 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- AFF1 | c.1486G>T p.E496* | Nonsense Mutation (SNP) | VAF 133/278 reads (48%) | called by muse, mutect2, varscan2
- AGAP5 | c.418C>A p.Q140K | Missense Mutation (SNP) | VAF 64/217 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- AIDA | c.440C>A p.S147Y | Missense Mutation (SNP) | VAF 105/216 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, varscan2
- AIDA | c.376G>T p.E126* | Nonsense Mutation (SNP) | VAF 88/204 reads (43%) | called by muse, varscan2
- AIM2 | c.380T>C p.V127A | Missense Mutation (SNP) | VAF 126/277 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AKAP9 | c.5158G>T p.E1720* | Nonsense Mutation (SNP) | VAF 26/52 reads (50%) | called by muse, mutect2, varscan2
- AKR1D1 | c.475G>T p.D159Y | Missense Mutation (SNP) | VAF 125/289 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- ALG14 | c.585C>A p.F195L | Missense Mutation (SNP) | VAF 127/260 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- AMELX | c.430C>A p.P144T | Missense Mutation (SNP) | VAF 378/783 reads (48%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AMER1 | c.970T>G p.S324A | Missense Mutation (SNP) | VAF 268/582 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- AMER1 | c.375C>A p.C125* | Nonsense Mutation (SNP) | VAF 66/637 reads (10%) | called by muse, mutect2
- ANK2 | c.10174T>A p.S3392T | Missense Mutation (SNP) | VAF 26/369 reads (7%) | SIFT tolerated, low confidence (0.28); PolyPhen probably damaging (0.991); called by muse, mutect2
- ANK3 | c.10833G>T p.M3611I | Missense Mutation (SNP) | VAF 147/331 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- ANK3 | c.5210C>A p.A1737D | Missense Mutation (SNP) | VAF 102/215 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ANKIB1 | c.2980G>T p.E994* | Nonsense Mutation (SNP) | VAF 170/361 reads (47%) | called by muse, mutect2, varscan2
- ANKRD11 | c.4130G>A p.G1377D | Missense Mutation (SNP) | VAF 55/378 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ANKRD20A1 | c.2030A>C p.K677T | Missense Mutation (SNP) | VAF 94/349 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.097); called by muse, mutect2
- ANKRD31 | c.4971dup p.S1658Ifs*10 | Frame Shift Ins (INS) | VAF 110/295 reads (37%) | called by mutect2, pindel, varscan2
- ANKRD31 | c.4259A>C p.K1420T | Missense Mutation (SNP) | VAF 48/374 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ANKRD40 | c.1068G>T p.R356S | Missense Mutation (SNP) | VAF 118/262 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- ANKRD42 | c.591C>A p.F197L | Missense Mutation (SNP) | VAF 145/287 reads (51%) | SIFT tolerated (0.68); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- ANKS6 | c.1524C>A p.S508R | Missense Mutation (SNP) | VAF 32/498 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2
- ANXA10 | c.476T>G p.V159G | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- AP1S2 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- APBA2 | c.1589C>A p.A530D | Missense Mutation (SNP) | VAF 309/569 reads (54%) | SIFT tolerated (0.05); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- APC | c.950C>A p.S317* | Nonsense Mutation (SNP) | VAF 45/269 reads (17%) | called by muse, mutect2, varscan2
- APC | c.3272dup p.H1092Tfs*27 | Frame Shift Ins (INS) | VAF 150/397 reads (38%) | called by mutect2, pindel, varscan2
- APC | c.6938C>A p.A2313D | Missense Mutation (SNP) | VAF 228/479 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- APC2 | c.5251C>A p.P1751T | Missense Mutation (SNP) | VAF 323/701 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- APOB | c.5881A>C p.S1961R | Missense Mutation (SNP) | VAF 148/308 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- ARFGAP3 | c.1526C>A p.S509* | Nonsense Mutation (SNP) | VAF 120/249 reads (48%) | called by muse, mutect2, varscan2
- ARHGAP11A | c.1942G>T p.D648Y | Missense Mutation (SNP) | VAF 59/150 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- ARHGAP12 | c.1084G>T p.E362* | Nonsense Mutation (SNP) | VAF 103/224 reads (46%) | called by muse, mutect2, varscan2
- ARHGAP15 | c.462G>T p.K154N | Missense Mutation (SNP) | VAF 128/274 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGAP31 | c.1784G>A p.S595N | Missense Mutation (SNP) | VAF 46/463 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2
- ARHGAP32 | c.1657T>C p.S553P (on ENST00000310343 / NM_001378025.1; = p.S204P on NM_014715.4) | Missense Mutation (SNP) | VAF 174/373 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ARHGAP5 | c.2000C>A p.S667* | Nonsense Mutation (SNP) | VAF 122/250 reads (49%) | called by muse, mutect2, varscan2
- ARHGEF18 | c.644A>G p.Q215R (on ENST00000359920 / NM_001130955.2; = p.Q111R on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 107/217 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ARHGEF6 | c.2205G>T p.M735I | Missense Mutation (SNP) | VAF 147/293 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ARID1A | c.3216dup p.W1073Mfs*32 | Frame Shift Ins (INS) | VAF 147/445 reads (33%) | called by mutect2, pindel, varscan2
- ARID2 | c.3485C>A p.T1162N | Missense Mutation (SNP) | VAF 163/321 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- ARID3C | c.43G>A p.G15R | Missense Mutation (SNP) | VAF 291/634 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- ARID4B | c.2308G>A p.V770I | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARL14EP | c.264A>C p.K88N | Missense Mutation (SNP) | VAF 19/210 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- ARMC8 | c.83T>G p.L28R (on ENST00000469044 / NM_001363941.2; = p.L14R on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/301 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ARMCX2 | c.1498A>C p.N500H | Missense Mutation (SNP) | VAF 134/312 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ARMCX2 | c.1337A>G p.E446G | Missense Mutation (SNP) | VAF 200/429 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ARNT | c.464A>C p.K155T | Missense Mutation (SNP) | VAF 134/348 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- ASCC3 | c.5141A>C p.K1714T | Missense Mutation (SNP) | VAF 111/234 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ASPN | c.515C>A p.S172* | Nonsense Mutation (SNP) | VAF 14/204 reads (7%) | called by muse, mutect2
- ASXL3 | c.5033G>A p.G1678D | Missense Mutation (SNP) | VAF 144/332 reads (43%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- ATF7IP | c.2038G>T p.D680Y | Missense Mutation (SNP) | VAF 92/213 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); called by muse, varscan2
- ATIC | c.1468G>A p.A490T | Missense Mutation (SNP) | VAF 153/323 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- ATP10B | c.3944T>G p.F1315C | Missense Mutation (SNP) | VAF 87/178 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- ATP13A1 | c.1818G>T p.E606D | Missense Mutation (SNP) | VAF 119/234 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ATP13A4 | c.3404T>C p.L1135P | Missense Mutation (SNP) | VAF 22/297 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- ATP1A4 | c.2449G>T p.D817Y | Missense Mutation (SNP) | VAF 142/289 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP2B3 | c.519C>A p.F173L | Missense Mutation (SNP) | VAF 306/755 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ATP2B3 | c.3405G>T p.K1135N | Missense Mutation (SNP) | VAF 196/648 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ATP6V0A4 | c.1562G>T p.G521V | Missense Mutation (SNP) | VAF 116/278 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP6V1F | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 161/325 reads (50%) | called by muse, mutect2, varscan2
- ATP7A | c.2141T>A p.L714* | Nonsense Mutation (SNP) | VAF 90/225 reads (40%) | called by muse, mutect2, varscan2
- ATP8B4 | c.3156T>G p.F1052L | Missense Mutation (SNP) | VAF 85/162 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATRNL1 | c.2876G>T p.G959V | Missense Mutation (SNP) | VAF 177/403 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AZI2 | c.238G>T p.E80* | Nonsense Mutation (SNP) | VAF 56/136 reads (41%) | called by muse, mutect2, varscan2
- B3GNT5 | c.513A>C p.K171N | Missense Mutation (SNP) | VAF 8/222 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BANK1 | c.397A>C p.S133R | Missense Mutation (SNP) | VAF 54/163 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- BCL9 | c.127G>T p.D43Y | Missense Mutation (SNP) | VAF 231/487 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BCL9 | c.3246G>T p.M1082I | Missense Mutation (SNP) | VAF 249/525 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BCLAF1 | c.2571T>G p.D857E | Missense Mutation (SNP) | VAF 129/301 reads (43%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- BEND4 | c.724A>G p.T242A | Missense Mutation (SNP) | VAF 168/330 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- BEX4 | c.181A>C p.N61H | Missense Mutation (SNP) | VAF 153/354 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4918A>C p.T1640P | Missense Mutation (SNP) | VAF 150/298 reads (50%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2, varscan2
- BLK | c.760G>T p.E254* | Nonsense Mutation (SNP) | VAF 144/313 reads (46%) | called by muse, mutect2, varscan2
- BOD1L1 | c.3648G>T p.M1216I | Missense Mutation (SNP) | VAF 96/232 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, varscan2
- BRD1 | c.505G>A p.V169I | Missense Mutation (SNP) | VAF 222/442 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- BRSK1 | c.697G>T p.D233Y | Missense Mutation (SNP) | VAF 197/432 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- BRWD1 | c.5086G>T p.E1696* | Nonsense Mutation (SNP) | VAF 86/230 reads (37%) | called by mutect2, varscan2
- BTBD8 | c.3260C>T p.T1087I (on ENST00000636805 / NM_001376131.1; = p.T574I on NM_015237.4) | Missense Mutation (SNP) | VAF 79/196 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C13orf42 | c.921G>T p.E307D | Missense Mutation (SNP) | VAF 189/352 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- C16orf89 | c.592T>A p.S198T | Missense Mutation (SNP) | VAF 176/391 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- C17orf80 | c.819G>T p.K273N | Missense Mutation (SNP) | VAF 130/254 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- C1D | c.189A>C p.L63F | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- C1GALT1C1 | c.349G>T p.D117Y | Missense Mutation (SNP) | VAF 24/399 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.384); called by muse, mutect2
- C1QTNF8 | c.102G>C p.W34C | Missense Mutation (SNP) | VAF 360/749 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- C1orf232 | c.206C>A p.S69* | Nonsense Mutation (SNP) | VAF 27/404 reads (7%) | called by muse, mutect2
- C20orf194 | c.1663T>A p.S555T | Missense Mutation (SNP) | VAF 13/259 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2
- C9orf72 | c.1348G>C p.A450P | Missense Mutation (SNP) | VAF 101/254 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CABLES2 | c.1294G>T p.D432Y | Missense Mutation (SNP) | VAF 129/266 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CABS1 | c.958A>G p.R320G | Missense Mutation (SNP) | VAF 111/266 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- CACNA1S | c.3008C>A p.A1003D | Missense Mutation (SNP) | VAF 227/473 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- CAD | c.3932C>A p.P1311H | Missense Mutation (SNP) | VAF 171/374 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CADM1 | c.1311G>T p.K437N | Missense Mutation (SNP) | VAF 95/178 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CALCOCO1 | c.136G>T p.D46Y | Missense Mutation (SNP) | VAF 158/318 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAMSAP1 | c.2938G>T p.A980S | Missense Mutation (SNP) | VAF 236/452 reads (52%) | SIFT tolerated (0.26); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- CAMSAP2 | c.448G>T p.E150* | Nonsense Mutation (SNP) | VAF 101/225 reads (45%) | called by mutect2, varscan2
- CAPS2 | c.1214C>A p.S405Y | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.03); called by mutect2, varscan2
- CAPS2 | c.948C>A p.F316L | Missense Mutation (SNP) | VAF 14/268 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); called by muse, mutect2
- CBFA2T2 | c.845G>T p.G282V | Missense Mutation (SNP) | VAF 279/614 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.122); called by muse, mutect2
- CCDC141 | c.2157C>A p.F719L | Missense Mutation (SNP) | VAF 159/367 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CCDC157 | c.802C>A p.P268T | Missense Mutation (SNP) | VAF 253/481 reads (53%) | SIFT tolerated (0.58); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- CCDC173 | c.91C>A p.Q31K | Missense Mutation (SNP) | VAF 86/219 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.01); called by muse, varscan2
- CCDC177 | c.695C>A p.S232* | Nonsense Mutation (SNP) | VAF 256/549 reads (47%) | called by muse, mutect2, varscan2
- CCDC18 | c.1083G>T p.M361I | Missense Mutation (SNP) | VAF 13/200 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CCDC73 | c.3161T>A p.L1054* | Nonsense Mutation (SNP) | VAF 71/174 reads (41%) | called by muse, mutect2, varscan2
- CCDC82 | c.190G>T p.D64Y | Missense Mutation (SNP) | VAF 69/164 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC88A | c.1366G>T p.E456* | Nonsense Mutation (SNP) | VAF 73/188 reads (39%) | called by muse, mutect2, varscan2
- CCDC88C | c.420C>A p.F140L | Missense Mutation (SNP) | VAF 126/255 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- CCNB3 | c.790G>T p.E264* | Nonsense Mutation (SNP) | VAF 160/372 reads (43%) | called by muse, mutect2, varscan2
- CCR6 | c.55T>G p.F19V | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.011); called by muse, mutect2
- CCSER1 | c.1007C>A p.S336* | Nonsense Mutation (SNP) | VAF 21/325 reads (6%) | called by muse, mutect2
- CD2 | c.1034C>A p.S345* | Nonsense Mutation (SNP) | VAF 165/375 reads (44%) | called by muse, mutect2, varscan2
- CD209 | c.624G>T p.E208D | Missense Mutation (SNP) | VAF 280/534 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by mutect2, varscan2
- CDC42BPG | c.2087G>A p.G696D | Missense Mutation (SNP) | VAF 49/350 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- CDH13 | c.89G>T p.G30V | Missense Mutation (SNP) | VAF 113/295 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDK20 | c.1039T>G p.*347Gext*92 (on ENST00000325303 / NM_001039803.3; = p.*326Gext*92 on NM_012119.4) | Nonstop Mutation (SNP) | VAF 11/311 reads (4%) | called by muse, mutect2
- CDS2 | c.728G>T p.G243V | Missense Mutation (SNP) | VAF 94/235 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CELSR2 | c.5488A>C p.N1830H | Missense Mutation (SNP) | VAF 183/370 reads (49%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- CENPE | c.5446G>A p.A1816T | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- CEP162 | c.3693G>T p.E1231D | Missense Mutation (SNP) | VAF 70/185 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CEP250 | c.2764G>T p.E922* | Nonsense Mutation (SNP) | VAF 53/255 reads (21%) | called by muse, mutect2, varscan2
- CEP290 | c.5434G>T p.E1812* | Nonsense Mutation (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- CES4A | c.1474A>C p.S492R (on ENST00000648724 / NM_001364782.1; = p.S394R on NM_001190201.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 196/386 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- CFAP43 | c.4465G>T p.E1489* | Nonsense Mutation (SNP) | VAF 28/72 reads (39%) | called by mutect2, varscan2
- CFAP47 | c.2576G>C p.R859T | Missense Mutation (SNP) | VAF 150/318 reads (47%) | SIFT tolerated (0.69); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- CFAP61 | c.2101C>A p.H701N | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CFAP70 | c.377C>A p.P126Q | Missense Mutation (SNP) | VAF 125/303 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- CFAP97D1 | c.274C>A p.P92T | Missense Mutation (SNP) | VAF 159/356 reads (45%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CGNL1 | c.3823G>T p.D1275Y | Missense Mutation (SNP) | VAF 32/526 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- CHD2 | c.2629G>T p.A877S | Missense Mutation (SNP) | VAF 191/393 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); called by muse, mutect2
- CHD3 | c.2149G>T p.D717Y | Missense Mutation (SNP) | VAF 93/204 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, varscan2
- CHD4 | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 166/336 reads (49%) | called by muse, mutect2, varscan2
- CHD8 | c.5295G>T p.M1765I (on ENST00000646647 / NM_001170629.2; = p.M1486I on NM_020920.4) | Missense Mutation (SNP) | VAF 228/446 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CHI3L2 | c.12del p.T5Pfs*11 | Frame Shift Del (DEL) | VAF 141/384 reads (37%) | called by mutect2, pindel, varscan2
- CKM | c.255C>A p.F85L | Missense Mutation (SNP) | VAF 173/401 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- CLASP2 | c.3767C>T p.A1256V (on ENST00000359576; = p.A1255V on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 83/187 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- CLCF1 | c.515G>T p.G172V | Missense Mutation (SNP) | VAF 31/633 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.006); called by muse, mutect2
- CLEC18A | c.364G>T p.E122* | Nonsense Mutation (SNP) | VAF 176/563 reads (31%) | called by muse, mutect2, varscan2
- CLEC20A | c.1012G>T p.E338* | Nonsense Mutation (SNP) | VAF 22/374 reads (6%) | called by muse, mutect2
- CLEC4F | c.1501G>T p.G501* | Nonsense Mutation (SNP) | VAF 196/375 reads (52%) | called by muse, mutect2, varscan2
- CMBL | c.291G>T p.W97C | Missense Mutation (SNP) | VAF 134/275 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CMIP | c.215T>C p.L72P | Missense Mutation (SNP) | VAF 267/539 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- CNKSR2 | c.1457G>T p.R486I | Missense Mutation (SNP) | VAF 10/195 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.387); called by muse, mutect2
- CNOT1 | c.6978C>A p.F2326L | Missense Mutation (SNP) | VAF 109/239 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CNP | c.218A>G p.K73R | Missense Mutation (SNP) | VAF 77/470 reads (16%) | SIFT tolerated (0.86); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CNST | c.1387C>A p.P463T | Missense Mutation (SNP) | VAF 151/314 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- CNTNAP4 | c.187A>T p.R63* | Nonsense Mutation (SNP) | VAF 127/275 reads (46%) | called by muse, mutect2, varscan2
- COL11A2 | c.2959C>A p.P987T (on ENST00000341947 / NM_080680.3; = p.P880T on NM_080679.2) | Missense Mutation (SNP) | VAF 208/476 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.922); called by mutect2, varscan2
- COL24A1 | c.2845G>T p.D949Y | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- COL4A5 | c.25G>T p.A9S | Missense Mutation (SNP) | VAF 240/488 reads (49%) | SIFT tolerated (0.39); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- COL6A5 | c.1924G>T p.E642* | Nonsense Mutation (SNP) | VAF 71/164 reads (43%) | called by muse, mutect2, varscan2
- COPS4 | c.603C>A p.F201L | Missense Mutation (SNP) | VAF 116/222 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CORIN | c.1755C>A p.F585L | Missense Mutation (SNP) | VAF 45/258 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- CPED1 | c.1643A>C p.K548T | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.068); called by muse, mutect2
- CPLANE1 | c.*1829+1G>T | Splice Site (SNP) | VAF 61/134 reads (46%) | called by muse, mutect2, varscan2
- CPXCR1 | c.235G>T p.D79Y | Missense Mutation (SNP) | VAF 36/518 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.32); called by muse, mutect2
- CRAMP1 | c.1355G>A p.S452N | Missense Mutation (SNP) | VAF 321/604 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- CRIPT | c.245T>G p.I82S | Missense Mutation (SNP) | VAF 71/173 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- CRISPLD2 | c.778G>T p.E260* | Nonsense Mutation (SNP) | VAF 224/516 reads (43%) | called by muse, mutect2
- CRLF2 | c.469G>T p.D157Y | Missense Mutation (SNP) | VAF 189/391 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CRYBG2 | c.200G>T p.G67V | Missense Mutation (SNP) | VAF 181/409 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSDE1 | c.516T>A p.S172R (on ENST00000358528 / NM_001007553.3; = p.S141R on NM_007158.6) | Missense Mutation (SNP) | VAF 82/188 reads (44%) | SIFT tolerated (0.68); PolyPhen benign (0.003); called by muse, varscan2
- CSMD1 | c.9227C>A p.A3076D (on ENST00000520002; = p.A3075D on NM_033225.6) | Missense Mutation (SNP) | VAF 31/453 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2
- CSMD1 | c.2111C>A p.P704H (on ENST00000520002; = p.P703H on NM_033225.6) | Missense Mutation (SNP) | VAF 140/285 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD3 | c.1507A>C p.S503R (on ENST00000297405 / NM_001363185.1; = p.S399R on NM_052900.3) | Missense Mutation (SNP) | VAF 68/139 reads (49%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSNKA2IP | c.674C>A p.S225* | Nonsense Mutation (SNP) | VAF 41/310 reads (13%) | called by muse, mutect2, varscan2
- CSNKA2IP | c.1360T>C p.F454L | Missense Mutation (SNP) | VAF 72/190 reads (38%) | SIFT tolerated, low confidence (0.49); PolyPhen possibly damaging (0.871); called by muse, mutect2
- CTR9 | c.1935G>T p.K645N | Missense Mutation (SNP) | VAF 104/271 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CUL2 | c.34G>T p.E12* | Nonsense Mutation (SNP) | VAF 95/228 reads (42%) | called by muse, mutect2, varscan2
- CUZD1 | c.193C>A p.P65T | Missense Mutation (SNP) | VAF 148/303 reads (49%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- CXorf38 | c.721G>T p.E241* | Nonsense Mutation (SNP) | VAF 113/271 reads (42%) | called by muse, mutect2, varscan2
- CXorf66 | c.552G>T p.K184N | Missense Mutation (SNP) | VAF 154/341 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CYP2E1 | c.979G>T p.E327* | Nonsense Mutation (SNP) | VAF 144/294 reads (49%) | called by muse, mutect2, varscan2
- CYP2U1 | c.214T>G p.F72V | Missense Mutation (SNP) | VAF 379/748 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DBF4B | c.656G>T p.R219I | Missense Mutation (SNP) | VAF 129/277 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- DCAF12L2 | c.606G>T p.W202C | Missense Mutation (SNP) | VAF 316/704 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCANP1 | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 86/446 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DDIAS | c.929A>T p.K310M | Missense Mutation (SNP) | VAF 109/241 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- DDX43 | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 14/190 reads (7%) | called by muse, mutect2
- DEFB115 | c.151G>T p.E51* | Nonsense Mutation (SNP) | VAF 96/237 reads (41%) | called by muse, mutect2, varscan2
- DENND3 | c.296G>T p.R99L | Missense Mutation (SNP) | VAF 45/425 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- DEPDC1 | c.1732C>A p.P578T | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DIS3L2 | c.225T>G p.I75M | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- DISP1 | c.2504G>T p.R835I | Missense Mutation (SNP) | VAF 219/436 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- DLG5 | c.4963T>G p.Y1655D | Missense Mutation (SNP) | VAF 109/235 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by mutect2, varscan2
- DLL3 | c.478del p.R160Gfs*81 | Frame Shift Del (DEL) | VAF 314/772 reads (41%) | called by mutect2, pindel, varscan2
- DLX3 | c.552C>A p.F184L | Missense Mutation (SNP) | VAF 187/422 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- DNAH1 | c.11196C>A p.C3732* | Nonsense Mutation (SNP) | VAF 218/437 reads (50%) | called by muse, varscan2
- DNAH12 | c.1445A>T p.N482I | Missense Mutation (SNP) | VAF 83/212 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- DNAH17 | c.749T>C p.V250A | Missense Mutation (SNP) | VAF 136/274 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- DNAH2 | c.11231T>G p.L3744R | Missense Mutation (SNP) | VAF 194/426 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNAH7 | c.4249G>T p.E1417* | Nonsense Mutation (SNP) | VAF 110/235 reads (47%) | called by muse, mutect2, varscan2
- DNAH8 | c.1605C>A p.F535L | Missense Mutation (SNP) | VAF 105/220 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- DNAJB6 | c.312T>G p.F104L | Missense Mutation (SNP) | VAF 76/199 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNM2 | c.1265A>G p.E422G | Missense Mutation (SNP) | VAF 218/446 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.02); called by muse, varscan2
- DNMT1 | c.691A>G p.T231A | Missense Mutation (SNP) | VAF 164/348 reads (47%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- DOCK10 | c.3643A>G p.N1215D | Missense Mutation (SNP) | VAF 119/233 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DOCK2 | c.4018C>A p.P1340T | Missense Mutation (SNP) | VAF 138/319 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DOCK8 | c.1830T>G p.F610L | Missense Mutation (SNP) | VAF 78/272 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); called by muse, mutect2
- DOP1A | c.5460G>T p.M1820I | Missense Mutation (SNP) | VAF 74/172 reads (43%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.885); called by mutect2, varscan2
- DOT1L | c.758T>C p.L253P | Missense Mutation (SNP) | VAF 137/414 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DPY19L2 | c.1840G>T p.E614* | Nonsense Mutation (SNP) | VAF 50/114 reads (44%) | called by muse, mutect2, varscan2
- DPY19L3 | c.452A>C p.K151T | Missense Mutation (SNP) | VAF 97/197 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- DSCAM | c.5727T>G p.F1909L | Missense Mutation (SNP) | VAF 95/235 reads (40%) | SIFT tolerated, low confidence (0.62); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- DSEL | c.2942G>T p.R981I | Missense Mutation (SNP) | VAF 136/288 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- DSP | c.1447A>T p.I483F | Missense Mutation (SNP) | VAF 148/344 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- DYNC1I2 | c.292G>T p.E98* | Nonsense Mutation (SNP) | VAF 130/309 reads (42%) | called by muse, mutect2, varscan2
- DYRK1A | c.1987A>T p.T663S | Missense Mutation (SNP) | VAF 203/428 reads (47%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0); called by muse, mutect2, varscan2
- DZIP1 | c.1438C>T p.H480Y (on ENST00000347108; = p.H461Y on NM_014934.5) | Missense Mutation (SNP) | VAF 13/265 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.043); called by muse, mutect2
- E2F7 | c.2445G>T p.Q815H | Missense Mutation (SNP) | VAF 173/352 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- EDC3 | c.107C>A p.S36Y | Missense Mutation (SNP) | VAF 174/386 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- EFCAB12 | c.1694C>A p.A565D | Missense Mutation (SNP) | VAF 160/307 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- EFCC1 | c.730G>T p.E244* | Nonsense Mutation (SNP) | VAF 268/528 reads (51%) | called by muse, mutect2, varscan2
- EFL1 | c.2593T>G p.L865V | Missense Mutation (SNP) | VAF 188/391 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- EGF | c.385G>T p.E129* | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- EIF3L | c.666G>T p.W222C | Missense Mutation (SNP) | VAF 152/343 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EIF4A2 | c.751T>G p.Y251D | Missense Mutation (SNP) | VAF 62/141 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- EIF4G3 | c.2415C>A p.F805L | Missense Mutation (SNP) | VAF 50/366 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- EIF5B | c.169G>C p.D57H | Missense Mutation (SNP) | VAF 119/220 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- ELF3 | c.653del p.D218Afs*36 | Frame Shift Del (DEL) | VAF 167/408 reads (41%) | called by mutect2, pindel, varscan2
- ELOVL3 | c.519G>T p.M173I | Missense Mutation (SNP) | VAF 207/415 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- ELP1 | c.405G>T p.M135I | Missense Mutation (SNP) | VAF 75/250 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ELP3 | c.1228G>T p.E410* | Nonsense Mutation (SNP) | VAF 102/237 reads (43%) | called by muse, mutect2, varscan2
- ELP5 | c.7C>A p.P3T | Missense Mutation (SNP) | VAF 160/334 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- EMC1 | c.1691T>G p.V564G | Missense Mutation (SNP) | VAF 223/482 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- ENOX2 | c.775T>A p.L259I (on ENST00000338144 / NM_001382520.1; = p.L230I on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 144/271 reads (53%) | SIFT tolerated (0.32); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EPHA7 | c.1219G>T p.A407S | Missense Mutation (SNP) | VAF 221/434 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- ERAS | c.212A>C p.D71A | Missense Mutation (SNP) | VAF 350/680 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ERBIN | c.1936G>T p.E646* | Nonsense Mutation (SNP) | VAF 43/114 reads (38%) | called by mutect2, varscan2
- ERCC6L | c.2647C>A p.Q883K | Missense Mutation (SNP) | VAF 81/234 reads (35%) | SIFT tolerated (0.64); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ERICH2 | c.16G>T p.E6* | Nonsense Mutation (SNP) | VAF 127/253 reads (50%) | called by muse, mutect2, varscan2
- ERICH2 | c.262T>A p.L88I | Missense Mutation (SNP) | VAF 11/280 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- ERO1A | c.654A>C p.L218F | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.225); called by muse, mutect2
- ERVV-2 | c.861T>G p.I287M | Missense Mutation (SNP) | VAF 80/426 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ETNK2 | c.798C>A p.F266L | Missense Mutation (SNP) | VAF 105/224 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- EVC2 | c.303G>T p.M101I | Missense Mutation (SNP) | VAF 118/234 reads (50%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- EVPLL | c.374C>A p.A125D | Missense Mutation (SNP) | VAF 98/229 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- EYA4 | c.754T>G p.Y252D | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- EZH2 | c.271T>C p.F91L | Missense Mutation (SNP) | VAF 133/254 reads (52%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- F10 | c.717G>T p.Q239H | Missense Mutation (SNP) | VAF 205/472 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- F8 | c.6256C>A p.P2086T | Missense Mutation (SNP) | VAF 149/294 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- FAM111B | c.1965T>G p.F655L | Missense Mutation (SNP) | VAF 138/304 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- FAM120C | c.3025G>A p.G1009R | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.757); called by muse, mutect2
- FAM171A1 | c.892A>G p.I298V | Missense Mutation (SNP) | VAF 93/209 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- FAM205A | c.2735A>G p.K912R | Missense Mutation (SNP) | VAF 156/351 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- FAM216A | c.693C>A p.F231L | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- FAM234B | c.1070C>A p.S357Y | Missense Mutation (SNP) | VAF 183/408 reads (45%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- FAN1 | c.824T>G p.L275* | Nonsense Mutation (SNP) | VAF 16/390 reads (4%) | called by muse, mutect2
- FANCA | c.3298C>A p.P1100T | Missense Mutation (SNP) | VAF 245/497 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- FAP | c.2226C>A p.N742K | Missense Mutation (SNP) | VAF 178/344 reads (52%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAT3 | c.2932G>T p.D978Y | Missense Mutation (SNP) | VAF 147/304 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAT3 | c.5665G>T p.E1889* | Nonsense Mutation (SNP) | VAF 12/306 reads (4%) | called by muse, mutect2
- FAT4 | c.3928G>T p.D1310Y | Missense Mutation (SNP) | VAF 77/160 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAT4 | c.8029A>C p.I2677L | Missense Mutation (SNP) | VAF 119/229 reads (52%) | SIFT tolerated (0.71); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FBN1 | c.2528C>A p.T843N | Missense Mutation (SNP) | VAF 24/240 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.233); called by muse, mutect2
- FBXO38 | c.682G>T p.D228Y | Missense Mutation (SNP) | VAF 66/170 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- FCAR | c.487G>T p.E163* | Nonsense Mutation (SNP) | VAF 213/458 reads (47%) | called by muse, mutect2, varscan2
- FCF1 | c.39G>T p.M13I | Missense Mutation (SNP) | VAF 144/342 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FER1L5 | c.4440C>A p.G1480= (on ENST00000623019; = p.G1453= on NM_001293083.2) | Splice Region (SNP) | VAF 29/245 reads (12%) | called by muse, mutect2, varscan2
- FGL1 | c.567G>T p.K189N | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- FHDC1 | c.481A>G p.R161G | Missense Mutation (SNP) | VAF 93/203 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- FHOD1 | c.2073G>T p.M691I | Missense Mutation (SNP) | VAF 168/368 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.246); called by muse, mutect2
- FIG4 | c.296T>C p.V99A | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); called by muse, mutect2
- FILIP1L | c.3379A>T p.T1127S (on ENST00000354552 / NM_182909.3; = p.T887S on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/166 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- FMNL2 | c.338C>A p.S113Y | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FNDC3A | c.2931G>T p.K977N (on ENST00000492622 / NM_001079673.2; = p.K921N on NM_014923.5) | Missense Mutation (SNP) | VAF 125/272 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- FOLH1 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- FSD2 | c.639G>A p.K213= | Splice Region (SNP) | VAF 80/163 reads (49%) | called by muse, mutect2, varscan2
- FSIP2 | c.8382G>T p.M2794I | Missense Mutation (SNP) | VAF 118/222 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- FSIP2 | c.8609C>A p.S2870* | Nonsense Mutation (SNP) | VAF 24/54 reads (44%) | called by muse, mutect2, varscan2
- FUBP1 | c.1836T>A p.S612R | Missense Mutation (SNP) | VAF 178/424 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FUBP3 | c.104C>A p.S35* | Nonsense Mutation (SNP) | VAF 76/177 reads (43%) | called by muse, mutect2, varscan2
- GAB3 | c.658G>T p.D220Y | Missense Mutation (SNP) | VAF 279/573 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- GARRE1 | c.1629C>A p.F543L | Missense Mutation (SNP) | VAF 222/509 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); called by muse, mutect2, varscan2
822 further variants in this file (551 protein-altering or splice-affecting, 210 silent, 61 other) are not listed here.
